Somatic mutation profile of cancer-model specimen HCM-BROD-0782-C71-85B (3D Neurosphere, passage 4; aliquot HCM-BROD-0782-C71-85B-01D-A87L-36), derived from the recurrence tumor of HCMI case HCM-BROD-0782-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 51.8 years (18,935 days).
Specimen HCM-BROD-0782-C71-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 04ae8c37-4abe-4b96-b1f3-5c80ae7782c9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0782-C71-10A (Blood Derived Normal), aliquot HCM-BROD-0782-C71-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/896a74b8-efaf-49f6-bdf0-e8875b5961bb

The open-access MAF lists 5,422 somatic variants for this specimen: 3,456 protein-altering or splice-affecting, 1,735 silent, 231 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3,161, Silent 1,735, Intron 145, Nonsense Mutation 126, Splice Site 93, Splice Region 63, 3'UTR 30, 5'UTR 26, RNA 11, 5'Flank 10, 3'Flank 9, Frame Shift Del 6.

Variants (750 of 5,422; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.6191C>T p.A2064V | Missense Mutation (SNP) | VAF 168/370 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.199); catalogued as rs1362964563; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DMD | c.2622+1G>A p.X874_splice | Splice Site (SNP) | VAF 84/183 reads (46%) | catalogued as rs398123901, CS013449; ClinVar: pathogenic; called by muse, mutect2, varscan2
- RYR1 | c.7373G>A p.R2458H | Missense Mutation (SNP) | VAF 179/393 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs121918594, CM118674, CM981783, COSV62093719; ClinVar: risk factor / pathogenic / drug response; called by muse, mutect2, varscan2
- SATB2 | c.1964C>T p.P655L | Missense Mutation (SNP) | VAF 217/465 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1553538919; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.313G>A p.G105S | Missense Mutation (SNP) | VAF 221/479 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.07); PolyPhen probably damaging (0.94); catalogued as rs1060501195, CM043949, COSV52726068, COSV52741717, COSV53015551; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- AAAS | c.106C>T p.P36S | Missense Mutation (SNP) | VAF 160/315 reads (51%) | SIFT tolerated (0.93); PolyPhen benign (0.186); catalogued as rs570362394; called by muse, mutect2, varscan2
- ABCA13 | c.1925C>T p.A642V | Missense Mutation (SNP) | VAF 99/292 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0.003); catalogued as rs775184311, COSV70043314; called by muse, mutect2, varscan2
- ABCA6 | c.3907G>A p.A1303T | Missense Mutation (SNP) | VAF 83/204 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs149559050; called by muse, varscan2
- ABCA8 | c.1111C>T p.L371F | Missense Mutation (SNP) | VAF 136/275 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.014); catalogued as COSV52194015; called by muse, mutect2, varscan2
- ABCA9 | c.260C>T p.T87I | Missense Mutation (SNP) | VAF 152/341 reads (45%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.729); catalogued as rs974409800; called by muse, mutect2, varscan2
- ABCB10 | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 155/330 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs757047846; called by muse, mutect2, varscan2
- ABCB5 | c.1492G>A p.A498T (on ENST00000404938 / NM_001163941.2; = p.A53T on NM_178559.6) | Missense Mutation (SNP) | VAF 141/366 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.331); catalogued as COSV99329913; called by muse, mutect2, varscan2
- ABCB8 | c.469G>A p.G157S (on ENST00000297504 / NM_001282291.2; = p.G140S on NM_007188.5) | Missense Mutation (SNP) | VAF 85/421 reads (20%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.593); catalogued as rs1396411687; called by muse, mutect2, varscan2
- ABCC12 | c.1693G>A p.E565K | Missense Mutation (SNP) | VAF 129/237 reads (54%) | SIFT tolerated (0.51); PolyPhen benign (0.145); catalogued as COSV60916024; called by muse, mutect2, varscan2
- ABCC8 | c.4288C>T p.L1430F | Missense Mutation (SNP) | VAF 184/392 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD112699, CM118069; called by muse, mutect2, varscan2
- AC004922.1 | c.1112G>A p.G371D | Missense Mutation (SNP) | VAF 150/540 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.305); catalogued as rs1443842051; called by muse, mutect2, varscan2
- ACACB | c.1206G>A p.W402* | Nonsense Mutation (SNP) | VAF 126/253 reads (50%) | catalogued as rs1246950867; called by muse, mutect2, varscan2
- ACACB | c.1672G>A p.V558M | Missense Mutation (SNP) | VAF 33/242 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs556775153, COSV58131001; called by muse, mutect2, varscan2
- ACBD4 | c.728G>A p.R243K (on ENST00000376955 / NM_001378111.1; = p.E246= on NM_024722.4) | Missense Mutation (SNP) | VAF 251/522 reads (48%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0); catalogued as rs377303243; called by muse, varscan2
- ACSL6 | c.506C>T p.T169I (on ENST00000379240; = p.T194I on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 126/290 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs765103893; called by muse, mutect2, varscan2
- ACSM5 | c.1207-1G>A p.X403_splice | Splice Site (SNP) | VAF 122/230 reads (53%) | catalogued as COSV100089460; called by muse, mutect2, varscan2
- ACSS3 | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 177/427 reads (41%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.911); catalogued as rs1013913366, COSV54089989; called by muse, mutect2, varscan2
- ACTL10 | c.485C>T p.T162I | Missense Mutation (SNP) | VAF 262/783 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV55776731; called by muse, mutect2, varscan2
- ACTL7B | c.680G>A p.G227D | Missense Mutation (SNP) | VAF 216/475 reads (45%) | SIFT deleterious (0.05); PolyPhen benign (0.129); catalogued as rs575244865, COSV65927475; called by muse, mutect2, varscan2
- ACTN4 | c.1384G>A p.D462N | Missense Mutation (SNP) | VAF 177/388 reads (46%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs760636941, COSV53150880; called by muse, mutect2, varscan2
- ADAMTS1 | c.1588G>A p.D530N | Missense Mutation (SNP) | VAF 215/438 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53172120; called by muse, mutect2, varscan2
- ADAMTS12 | c.4636G>A p.A1546T | Missense Mutation (SNP) | VAF 120/249 reads (48%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV61274127; called by muse, mutect2, varscan2
- ADAMTS13 | c.313C>T p.L105F | Missense Mutation (SNP) | VAF 162/313 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs782488906; called by muse, mutect2, varscan2
- ADAMTS3 | c.1831G>A p.D611N | Missense Mutation (SNP) | VAF 223/434 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99710704; called by muse, mutect2, varscan2
- ADAMTS4 | c.2041G>A p.D681N | Missense Mutation (SNP) | VAF 156/346 reads (45%) | SIFT tolerated (0.51); PolyPhen benign (0.021); catalogued as rs1298138755; called by muse, mutect2, varscan2
- ADAMTS6 | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 130/270 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66863436; called by muse, mutect2, varscan2
- ADAMTS9 | c.5462C>T p.A1821V | Missense Mutation (SNP) | VAF 184/386 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as COSV99900190; called by muse, mutect2, varscan2
- ADAR | c.1921G>A p.A641T | Missense Mutation (SNP) | VAF 136/309 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1251528383; called by muse, mutect2, varscan2
- ADARB1 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 224/465 reads (48%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.524); catalogued as rs1355513858, COSV62343576; called by muse, mutect2, varscan2
- ADARB2 | c.1831G>A p.A611T | Missense Mutation (SNP) | VAF 251/543 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.005); catalogued as COSV101184551; called by muse, mutect2, varscan2
- ADCK1 | c.1055C>T p.S352F | Missense Mutation (SNP) | VAF 198/375 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as rs1295572743, COSV53083101; called by muse, mutect2, varscan2
- ADGRA3 | c.1630G>A p.A544T | Missense Mutation (SNP) | VAF 140/274 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.073); catalogued as rs1479232242; called by muse, mutect2, varscan2
- ADGRD1 | c.1099G>A p.G367S | Missense Mutation (SNP) | VAF 177/341 reads (52%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV55449750; called by muse, mutect2, varscan2
- ADGRG2 | c.2119G>A p.V707I (on ENST00000379869 / NM_001079858.3; = p.V704I on NM_005756.4) | Missense Mutation (SNP) | VAF 231/480 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV61340286; called by muse, mutect2, varscan2
- ADGRL2 | c.46G>A p.V16I | Missense Mutation (SNP) | VAF 104/266 reads (39%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs376600105; called by muse, mutect2, varscan2
- ADGRV1 | c.7798G>A p.E2600K | Missense Mutation (SNP) | VAF 182/337 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1010846236; called by muse, mutect2, varscan2
- ADORA1 | c.564G>A p.W188* | Nonsense Mutation (SNP) | VAF 236/446 reads (53%) | catalogued as COSV55141421; called by muse, mutect2, varscan2
- AFF3 | c.2843C>T p.P948L | Missense Mutation (SNP) | VAF 189/368 reads (51%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs1347906445, COSV100418230; called by muse, mutect2, varscan2
- AGBL5 | c.721G>A p.G241S | Missense Mutation (SNP) | VAF 131/307 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs950361281; called by muse, mutect2, varscan2
- AGFG1 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 209/393 reads (53%) | SIFT tolerated (0.49); PolyPhen benign (0.011); catalogued as rs749693668; called by muse, mutect2, varscan2
- AGGF1 | c.1310G>A p.G437E | Missense Mutation (SNP) | VAF 94/192 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57228910; called by muse, mutect2, varscan2
- AGO1 | c.1277C>T p.A426V | Missense Mutation (SNP) | VAF 141/290 reads (49%) | SIFT tolerated (0.17); PolyPhen benign (0.009); catalogued as COSV100940931; called by muse, mutect2, varscan2
- AGRN | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 186/436 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV65071842; called by muse, mutect2, varscan2
- AHNAK | c.15923G>A p.G5308E | Missense Mutation (SNP) | VAF 202/416 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs936227250; called by muse, mutect2, varscan2
- AHNAK | c.14008C>T p.P4670S | Missense Mutation (SNP) | VAF 206/427 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.984); catalogued as COSV99946898; called by muse, mutect2, varscan2
- AIP | c.659C>T p.S220F | Missense Mutation (SNP) | VAF 150/298 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs1488470719; called by muse, mutect2, varscan2
- AKAP11 | c.5386C>T p.H1796Y | Missense Mutation (SNP) | VAF 101/218 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.243); catalogued as rs1486222874, COSV50305382; called by muse, mutect2, varscan2
- AKAP17A | c.602G>A p.G201D | Missense Mutation (SNP) | VAF 360/797 reads (45%) | SIFT tolerated (0.1); PolyPhen benign (0.073); catalogued as rs371229940; called by muse, mutect2
- AKAP3 | c.374C>T p.S125F | Missense Mutation (SNP) | VAF 127/301 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99962354; called by muse, mutect2, varscan2
- AKAP9 | c.5771C>A p.S1924Y (on ENST00000359028; = p.S1892Y on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 151/555 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.026); catalogued as COSV62339086; called by muse, mutect2, varscan2
- AKAP9 | c.11347C>T p.P3783S (on ENST00000359028; = p.P3759S on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 214/684 reads (31%) | SIFT tolerated (0.81); PolyPhen benign (0.195); catalogued as COSV62344419; called by muse, mutect2, varscan2
- AKR1B15 | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 126/480 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.211); catalogued as COSV71152476; called by muse, varscan2
- AKR1C2 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 149/350 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs200268088; called by muse, mutect2, varscan2
- AKR1E2 | c.838G>A p.V280M | Missense Mutation (SNP) | VAF 151/287 reads (53%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1330004805; called by muse, mutect2, varscan2
- AL096814.1 | c.335G>A p.R112H | Missense Mutation (SNP) | VAF 168/347 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs571124702; called by muse, mutect2, varscan2
- AL121758.1 | c.256C>T p.P86S | Missense Mutation (SNP) | VAF 173/523 reads (33%) | PolyPhen possibly damaging (0.81); catalogued as rs142840348; called by muse, mutect2, varscan2
- ALK | c.4481G>A p.G1494E | Missense Mutation (SNP) | VAF 192/440 reads (44%) | SIFT tolerated (0.06); PolyPhen benign (0.344); catalogued as rs368484630; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ALOX15 | c.807+1G>A p.X269_splice | Splice Site (SNP) | VAF 28/106 reads (26%) | catalogued as rs1233527451; called by muse, mutect2, varscan2
- ALOX15 | c.587G>A p.C196Y | Missense Mutation (SNP) | VAF 185/416 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.361); catalogued as rs761134127; called by muse, mutect2, varscan2
- AMER1 | c.2266G>A p.E756K | Missense Mutation (SNP) | VAF 285/580 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.081); catalogued as COSV57655361; called by muse, mutect2, varscan2
- AMOTL2 | c.1420G>A p.E474K | Missense Mutation (SNP) | VAF 295/581 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV99998205; called by muse, mutect2, varscan2
- ANGPT2 | c.707C>T p.T236I | Missense Mutation (SNP) | VAF 118/246 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.109); catalogued as rs1319667380; called by muse, varscan2
- ANGPT2 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 120/254 reads (47%) | SIFT deleterious (0.04); PolyPhen benign (0.013); catalogued as rs1342611009; called by muse, varscan2
- ANGPTL4 | c.1010G>A p.R337K | Missense Mutation (SNP) | VAF 175/343 reads (51%) | SIFT tolerated (0.43); PolyPhen benign (0.101); catalogued as rs1568218762; called by muse, mutect2, varscan2
- ANK2 | c.6625G>A p.G2209R | Missense Mutation (SNP) | VAF 163/336 reads (49%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.734); catalogued as COSV52190266; called by muse, mutect2, varscan2
- ANKRD10 | c.1106G>A p.G369E | Missense Mutation (SNP) | VAF 174/353 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as rs1289308598; called by muse, mutect2, varscan2
- ANKRD6 | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 157/315 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); catalogued as rs375580615; called by muse, mutect2
- ANO4 | c.929C>T p.T310I (on ENST00000392977 / NM_001286615.2; = p.T275I on NM_178826.4) | Missense Mutation (SNP) | VAF 129/330 reads (39%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.859); catalogued as COSV54597158; called by muse, mutect2, varscan2
- ANTXR1 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 131/306 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs1271409204; called by muse, mutect2, varscan2
- AOAH | c.727C>T p.P243S | Missense Mutation (SNP) | VAF 132/322 reads (41%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.996); catalogued as COSV51735544; called by muse, mutect2, varscan2
- AOC1 | c.58G>A p.E20K | Missense Mutation (SNP) | VAF 243/802 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as rs571251831, COSV62871462; called by muse, mutect2, varscan2
- AP1B1 | c.2341G>A p.V781I | Missense Mutation (SNP) | VAF 205/205 reads (100%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs746583431; called by muse, mutect2, varscan2
- AP1G1 | c.1483G>A p.E495K | Missense Mutation (SNP) | VAF 124/279 reads (44%) | SIFT tolerated (0.55); PolyPhen benign (0.23); catalogued as COSV55495337; called by muse, varscan2
- AP4E1 | c.2878G>A p.E960K | Missense Mutation (SNP) | VAF 84/193 reads (44%) | SIFT tolerated (0.25); PolyPhen benign (0.272); catalogued as COSV55915637; called by muse, mutect2, varscan2
- AP5M1 | c.997G>A p.V333I | Missense Mutation (SNP) | VAF 59/59 reads (100%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs772478374; called by muse, mutect2, varscan2
- APBA3 | c.1183G>A p.V395M | Missense Mutation (SNP) | VAF 213/379 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1240205380; called by muse, mutect2, varscan2
- APC | c.3973G>A p.A1325T | Missense Mutation (SNP) | VAF 187/362 reads (52%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV104439191; called by muse, mutect2, varscan2
- APC | c.8348C>T p.P2783L | Missense Mutation (SNP) | VAF 185/380 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57320808; called by muse, mutect2, varscan2
- APC2 | c.6811C>T p.P2271S | Missense Mutation (SNP) | VAF 236/542 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.08); catalogued as rs771322265; called by muse, mutect2, varscan2
- APCDD1 | c.719C>T p.T240I | Missense Mutation (SNP) | VAF 167/361 reads (46%) | SIFT deleterious (0.04); PolyPhen benign (0.062); catalogued as COSV62373246; called by muse, mutect2, varscan2
- APMAP | c.44C>T p.P15L | Missense Mutation (SNP) | VAF 203/624 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.737); catalogued as rs779302394; called by muse, mutect2, varscan2
- APOB | c.2414C>T p.T805I | Missense Mutation (SNP) | VAF 202/419 reads (48%) | SIFT tolerated (0.06); PolyPhen benign (0.092); catalogued as rs1291440333, COSV51949113; called by muse, mutect2, varscan2
- ARAF | c.550G>A p.G184S | Missense Mutation (SNP) | VAF 168/381 reads (44%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs958730062; called by muse, mutect2, varscan2
- ARAF | c.1763G>A p.R588H | Missense Mutation (SNP) | VAF 205/445 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776912006, COSV51694793; called by muse, mutect2, varscan2
- ARFIP1 | c.1097C>T p.A366V (on ENST00000353617 / NM_001287432.1; = p.A334V on NM_014447.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 149/276 reads (54%) | SIFT tolerated (0.28); PolyPhen benign (0.012); catalogued as COSV100617093; called by muse, mutect2, varscan2
- ARHGAP18 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 138/283 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.007); catalogued as COSV63763210; called by muse, mutect2, varscan2
- ARHGAP23 | c.1412C>T p.P471L | Missense Mutation (SNP) | VAF 380/819 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.005); catalogued as rs939981793; called by muse, mutect2, varscan2
- ARHGAP30 | c.442C>T p.L148F | Missense Mutation (SNP) | VAF 137/268 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63519433; called by muse, mutect2, varscan2
- ARHGAP9 | c.1663G>A p.V555M (on ENST00000393797 / NM_001319850.2; = p.V536M on NM_032496.4) | Missense Mutation (SNP) | VAF 108/310 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99953983; called by muse, mutect2, varscan2
- ARHGEF18 | c.2527G>A p.G843S (on ENST00000359920 / NM_001130955.2; = p.G739S on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 315/623 reads (51%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1050542397; called by muse, mutect2, varscan2
- ARHGEF26 | c.1799C>T p.S600F | Missense Mutation (SNP) | VAF 130/286 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100726544; called by muse, mutect2, varscan2
- ARHGEF35 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 32/820 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as COSV100967659; called by muse, mutect2
- ARHGEF40 | c.2434G>A p.D812N | Missense Mutation (SNP) | VAF 134/291 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV53885033; called by muse, mutect2, varscan2
- ARID1A | c.1867G>A p.G623R | Missense Mutation (SNP) | VAF 128/270 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.742); catalogued as rs267598525, COSV61386313, COSV61387945; called by muse, mutect2, varscan2
- ARID3C | c.1139G>A p.G380D | Missense Mutation (SNP) | VAF 206/206 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs909856493; called by muse, mutect2, varscan2
- ARMC9 | c.2270C>T p.A757V | Missense Mutation (SNP) | VAF 153/309 reads (50%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as rs749001648; called by muse, mutect2, varscan2
- ARMH1 | c.937G>A p.D313N | Missense Mutation (SNP) | VAF 169/339 reads (50%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1163039804; called by muse, mutect2, varscan2
- ASIC4 | c.1531C>T p.P511S (on ENST00000347842 / NM_182847.3; = p.P530S on NM_018674.6) | Missense Mutation (SNP) | VAF 202/389 reads (52%) | SIFT tolerated (0.6); PolyPhen benign (0.026); catalogued as COSV99704775; called by muse, mutect2, varscan2
- ASPSCR1 | c.863G>A p.G288D | Missense Mutation (SNP) | VAF 258/537 reads (48%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.966); catalogued as COSV100144689; called by muse, mutect2, varscan2
- ASXL1 | c.2845G>A p.G949S | Missense Mutation (SNP) | VAF 224/688 reads (33%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.012); catalogued as COSV60103389, COSV60107039; called by muse, varscan2
- ATF6B | c.1504C>T p.R502W | Missense Mutation (SNP) | VAF 171/324 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs777403820; called by muse, mutect2, varscan2
- ATG2A | c.4795G>A p.D1599N | Missense Mutation (SNP) | VAF 179/350 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1176128409; called by muse, mutect2, varscan2
- ATG9A | c.2216G>A p.G739E | Missense Mutation (SNP) | VAF 253/544 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.346); catalogued as COSV54694772; called by muse, mutect2, varscan2
- ATP10A | c.2050G>A p.E684K | Missense Mutation (SNP) | VAF 230/482 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0.1); catalogued as COSV100791431; called by muse, mutect2, varscan2
- ATP13A4 | c.2528T>C p.V843A | Missense Mutation (SNP) | VAF 171/325 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs746685890; called by muse, mutect2, varscan2
- ATP13A5 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 148/324 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100665223; called by muse, mutect2, varscan2
- ATP23 | c.646C>T p.H216Y | Missense Mutation (SNP) | VAF 251/520 reads (48%) | SIFT tolerated (0.6); PolyPhen benign (0.007); catalogued as rs759939601; called by muse, mutect2, varscan2
- ATP2A2 | c.1574C>T p.T525I | Missense Mutation (SNP) | VAF 185/353 reads (52%) | SIFT deleterious (0.01); PolyPhen benign (0.078); catalogued as rs918160280; called by muse, mutect2, varscan2
- ATP6V0A1 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 209/473 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.287); catalogued as COSV52872534; called by muse, mutect2, varscan2
- ATP6V0A2 | c.76C>T p.L26F | Missense Mutation (SNP) | VAF 174/371 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as rs749862652; called by muse, mutect2, varscan2
- ATP6V1H | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 168/326 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); catalogued as rs762638066, COSV100778625; called by muse, mutect2, varscan2
- ATP7B | c.814G>A p.V272I | Missense Mutation (SNP) | VAF 171/364 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as rs771501259; called by muse, mutect2, varscan2
- ATP8A1 | c.2479G>A p.A827T | Missense Mutation (SNP) | VAF 143/307 reads (47%) | SIFT tolerated (0.47); PolyPhen benign (0.078); catalogued as rs1235702284, COSV52552388; called by muse, mutect2, varscan2
- ATRX | c.7112C>T p.A2371V | Missense Mutation (SNP) | VAF 124/332 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.825); catalogued as COSV64879839; called by muse, mutect2, varscan2
- AUTS2 | c.2977C>T p.P993S | Missense Mutation (SNP) | VAF 212/743 reads (29%) | SIFT tolerated (0.51); PolyPhen benign (0.022); catalogued as rs1317631817; called by muse, mutect2, varscan2
- AWAT1 | c.359C>T p.A120V | Missense Mutation (SNP) | VAF 277/609 reads (45%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as rs1287143654; called by muse, varscan2
- AXIN1 | c.1342C>T p.P448S | Missense Mutation (SNP) | VAF 300/657 reads (46%) | SIFT tolerated (0.16); PolyPhen benign (0.02); catalogued as rs1325540001; called by muse, mutect2, varscan2
- BAHCC1 | c.7534G>A p.E2512K | Missense Mutation (SNP) | VAF 272/542 reads (50%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs782458721; called by muse, mutect2, varscan2
- BAIAP2L1 | c.679G>A p.E227K | Missense Mutation (SNP) | VAF 140/531 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.179); catalogued as rs372690052, COSV50060388; called by muse, mutect2, varscan2
- BAK1 | c.443C>T p.T148I | Missense Mutation (SNP) | VAF 200/437 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.175); catalogued as rs373714419; called by muse, mutect2, varscan2
- BAZ2B | c.5272G>A p.A1758T | Missense Mutation (SNP) | VAF 84/214 reads (39%) | SIFT tolerated (0.29); PolyPhen benign (0.023); catalogued as rs970512015; called by muse, mutect2, varscan2
- BCKDK | c.247G>A p.D83N | Missense Mutation (SNP) | VAF 180/383 reads (47%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs1567428269; called by muse, mutect2, varscan2
- BEND4 | c.1496C>T p.A499V | Missense Mutation (SNP) | VAF 254/501 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as rs759939750, COSV101549753; called by muse, mutect2, varscan2
- BEST4 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 290/555 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1220210615; called by muse, mutect2, varscan2
- BICD2 | c.1525G>A p.V509M | Missense Mutation (SNP) | VAF 229/458 reads (50%) | SIFT tolerated (0.25); PolyPhen benign (0.07); catalogued as rs528418006; called by muse, mutect2, varscan2
- BICDL2 | c.1058C>T p.A353V | Missense Mutation (SNP) | VAF 152/381 reads (40%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs770962990, COSV104390876, COSV54158266; called by muse, mutect2, varscan2
- BLK | c.1046C>T p.A349V | Missense Mutation (SNP) | VAF 120/250 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.724); catalogued as rs759976637; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BNIP5 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 140/272 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.208); catalogued as rs149597798; called by muse, varscan2
- BOD1L1 | c.6155G>A p.S2052N | Missense Mutation (SNP) | VAF 175/370 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.079); catalogued as rs751069341; called by muse, mutect2, varscan2
- BOD1L2 | c.466C>T p.P156S | Missense Mutation (SNP) | VAF 104/223 reads (47%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.559); catalogued as rs1458390377; called by muse, mutect2, varscan2
- BOK | c.391G>A p.A131T | Missense Mutation (SNP) | VAF 194/413 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs141191357; called by muse, mutect2, varscan2
- BORA | c.557C>T p.P186L (on ENST00000613797; = p.P111L on NM_024808.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64695380; called by muse, mutect2, varscan2
- BPIFB4 | c.302G>A p.G101D | Missense Mutation (SNP) | VAF 200/572 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV64951801; called by muse, mutect2, varscan2
- BPIFB4 | c.1753G>A p.G585S | Missense Mutation (SNP) | VAF 136/401 reads (34%) | SIFT tolerated (0.19); PolyPhen probably damaging (1); catalogued as COSV64951893; called by muse, mutect2, varscan2
- BRCA1 | c.1729G>A p.E577K | Missense Mutation (SNP) | VAF 173/375 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.688); catalogued as CM055099, COSV58799692; called by muse, mutect2, varscan2
- BRD3 | c.485G>A p.G162E | Missense Mutation (SNP) | VAF 146/322 reads (45%) | SIFT tolerated (0.27); PolyPhen benign (0.179); catalogued as rs778987863; called by muse, mutect2, varscan2
- BRI3 | c.344G>A p.R115Q | Missense Mutation (SNP) | VAF 149/544 reads (27%) | SIFT tolerated (0.12); PolyPhen benign (0.195); catalogued as rs137943501; called by muse, mutect2, varscan2
- BSN | c.6020G>A p.G2007D | Missense Mutation (SNP) | VAF 221/424 reads (52%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as rs764776662, COSV56514595; called by muse, mutect2, varscan2
- BTBD7 | c.2351C>T p.P784L | Missense Mutation (SNP) | VAF 217/490 reads (44%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); catalogued as rs1453199802; called by muse, mutect2, varscan2
- BTBD9 | c.1371G>A p.W457* | Nonsense Mutation (SNP) | VAF 162/346 reads (47%) | catalogued as rs1188001291, COSV58435137; called by muse, mutect2, varscan2
- BTN2A1 | c.583C>T p.P195S | Missense Mutation (SNP) | VAF 170/344 reads (49%) | SIFT tolerated (0.22); PolyPhen benign (0.122); catalogued as rs746933028; called by muse, mutect2, varscan2
- BTN2A1 | c.1046G>A p.S349N | Missense Mutation (SNP) | VAF 120/303 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as rs769925071; called by muse, mutect2, varscan2
- BTNL9 | c.947G>A p.G316D | Missense Mutation (SNP) | VAF 185/375 reads (49%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.756); catalogued as COSV59793544; called by muse, mutect2, varscan2
- C12orf29 | c.790-1G>A p.X264_splice | Splice Site (SNP) | VAF 121/294 reads (41%) | catalogued as COSV100467739; called by muse, mutect2, varscan2
- C12orf50 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 154/300 reads (51%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.564); catalogued as rs755953602; called by muse, mutect2, varscan2
- C20orf203 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 120/370 reads (32%) | SIFT tolerated, low confidence (0.45); PolyPhen possibly damaging (0.497); catalogued as rs763432239; called by muse, mutect2, varscan2
- C2CD5 | c.779C>T p.S260F | Missense Mutation (SNP) | VAF 131/274 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.854); catalogued as COSV61728609; called by muse, mutect2, varscan2
- C2orf16 | c.5251C>T p.H1751Y | Missense Mutation (SNP) | VAF 214/463 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.253); catalogued as rs555322236, COSV62677155; called by mutect2, varscan2
- C5AR2 | c.423G>A p.W141* | Nonsense Mutation (SNP) | VAF 205/434 reads (47%) | catalogued as rs764803148; called by muse, mutect2, varscan2
- C9 | c.1298C>T p.T433I | Missense Mutation (SNP) | VAF 157/351 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV54682076; called by muse, mutect2, varscan2
- CAB39L | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 122/308 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.222); catalogued as rs775224456; called by muse, mutect2, varscan2
- CACNA1H | c.1120G>A p.V374M | Missense Mutation (SNP) | VAF 138/341 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1415166471, COSV62002704; called by muse, mutect2, varscan2
- CACNA1S | c.366G>A p.W122* | Nonsense Mutation (SNP) | VAF 190/381 reads (50%) | catalogued as COSV62939767; called by muse, mutect2, varscan2
- CACNG2 | c.482C>T p.A161V | Missense Mutation (SNP) | VAF 186/186 reads (100%) | SIFT tolerated (0.23); PolyPhen benign (0.383); catalogued as rs1021475125; called by muse, mutect2, varscan2
- CAD | c.470C>T p.P157L | Missense Mutation (SNP) | VAF 170/345 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs749788077; called by muse, mutect2, varscan2
- CADPS2 | c.1660G>A p.G554S | Missense Mutation (SNP) | VAF 28/417 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.843); catalogued as COSV57386159; called by muse, mutect2
- CALHM3 | c.245G>A p.R82H | Missense Mutation (SNP) | VAF 151/155 reads (97%) | SIFT tolerated (0.29); PolyPhen benign (0.077); catalogued as rs545873363; called by muse, mutect2, varscan2
- CAMKMT | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 199/448 reads (44%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs989336819; called by muse, mutect2, varscan2
- CAND1 | c.271C>T p.L91F | Missense Mutation (SNP) | VAF 155/314 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.384); catalogued as rs545940488, COSV101598283; called by muse, mutect2, varscan2
- CAPZA2 | c.813G>A p.W271* | Nonsense Mutation (SNP) | VAF 134/531 reads (25%) | catalogued as COSV100753853; called by muse, mutect2, varscan2
- CARD9 | c.862C>T p.R288W | Missense Mutation (SNP) | VAF 282/616 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.65); catalogued as rs770668488, COSV59996114; called by muse, mutect2, varscan2
- CARNS1 | c.2360G>A p.C787Y | Missense Mutation (SNP) | VAF 283/591 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as rs1475110306, COSV57053676; called by muse, mutect2, varscan2
- CASKIN1 | c.1150+1G>A p.X384_splice | Splice Site (SNP) | VAF 111/270 reads (41%) | catalogued as COSV58872978; called by muse, mutect2, varscan2
- CCBE1 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 216/461 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.761); catalogued as rs747380899; called by muse, mutect2, varscan2
- CCDC112 | c.1179G>A p.K393= | Splice Region (SNP) | VAF 76/166 reads (46%) | catalogued as rs781598493; called by muse, mutect2, varscan2
- CCDC136 | c.3281G>A p.S1094N | Missense Mutation (SNP) | VAF 49/600 reads (8%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs576782522; called by muse, mutect2
- CCDC15 | c.2126C>T p.S709F | Missense Mutation (SNP) | VAF 80/205 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs750991622; called by muse, mutect2, varscan2
- CCDC157 | c.196C>T p.P66S | Missense Mutation (SNP) | VAF 275/276 reads (100%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.973); catalogued as COSV57837560; called by muse, mutect2, varscan2
- CCDC158 | c.2938G>A p.V980I | Missense Mutation (SNP) | VAF 78/197 reads (40%) | SIFT tolerated (0.37); PolyPhen benign (0.036); catalogued as rs774374758; called by muse, mutect2, varscan2
- CCDC168 | c.21102G>T p.W7034C | Missense Mutation (SNP) | VAF 177/372 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs926319791; called by muse, mutect2, varscan2
- CCDC30 | c.1007C>T p.A336V (on ENST00000340612; = p.A293V on NM_001080850.3) | Missense Mutation (SNP) | VAF 138/316 reads (44%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.746); catalogued as rs1217676930; called by muse, mutect2, varscan2
- CCDC33 | c.568G>A p.E190K | Missense Mutation (SNP) | VAF 175/372 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.737); catalogued as rs948372186, COSV58348124; called by muse, mutect2, varscan2
- CCDC65 | c.195G>A p.W65* | Nonsense Mutation (SNP) | VAF 217/396 reads (55%) | catalogued as rs948326397; called by muse, mutect2, varscan2
- CCL2 | c.116C>T p.T39I | Missense Mutation (SNP) | VAF 139/330 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.021); catalogued as rs1365264424, COSV99861583; called by muse, mutect2, varscan2
- CCNB3 | c.3670C>T p.R1224C | Missense Mutation (SNP) | VAF 179/386 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs782145357, COSV52070254; called by muse, mutect2, varscan2
- CCP110 | c.910G>A p.G304S | Missense Mutation (SNP) | VAF 170/352 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.147); catalogued as COSV101195198; called by muse, mutect2, varscan2
- CCS | c.489G>A p.R163= | Splice Region (SNP) | VAF 147/342 reads (43%) | catalogued as COSV59579125; called by muse, mutect2, varscan2
- CD163 | c.1978G>A p.G660R | Missense Mutation (SNP) | VAF 256/479 reads (53%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.978); catalogued as rs965071363; called by muse, mutect2, varscan2
- CD164L2 | c.293G>A p.G98D | Missense Mutation (SNP) | VAF 151/398 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.162); catalogued as rs753852121; called by muse, mutect2, varscan2
- CD1B | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 162/372 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as rs760467639; called by muse, varscan2
- CD48 | c.640C>T p.P214S | Missense Mutation (SNP) | VAF 226/468 reads (48%) | SIFT tolerated (0.08); PolyPhen benign (0.125); catalogued as rs1342111173; called by muse, mutect2, varscan2
- CD68 | c.146C>T p.T49I | Missense Mutation (SNP) | VAF 268/528 reads (51%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.822); catalogued as rs770479505; called by muse, mutect2, varscan2
- CD79B | c.389C>T p.S130L | Missense Mutation (SNP) | VAF 167/393 reads (42%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as rs1389559363, COSV50076538; called by muse, mutect2, varscan2
- CDC20B | c.737C>T p.A246V | Missense Mutation (SNP) | VAF 178/335 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1379606514, COSV57057190; called by muse, mutect2, varscan2
- CDC27 | c.1929G>A p.M643I | Missense Mutation (SNP) | VAF 103/250 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as COSV99294549; called by muse, mutect2, varscan2
- CDH1 | c.833G>A p.G278E | Missense Mutation (SNP) | VAF 136/291 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs1555515597, COSV99931793; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CDH11 | c.1916C>T p.T639I | Missense Mutation (SNP) | VAF 131/298 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.266); catalogued as COSV51755614; called by muse, mutect2, varscan2
- CDH18 | c.592G>A p.V198I | Missense Mutation (SNP) | VAF 99/220 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.683); catalogued as rs184208296; called by muse, varscan2
- CDH5 | c.1382C>T p.S461F | Missense Mutation (SNP) | VAF 133/261 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV58519973; called by muse, mutect2, varscan2
- CDH9 | c.973C>T p.Q325* | Nonsense Mutation (SNP) | VAF 134/320 reads (42%) | catalogued as COSV99144396; called by muse, mutect2, varscan2
- CDK13 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 98/600 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.563); catalogued as rs1183040112; called by mutect2, varscan2
- CDNF | c.418C>T p.R140W | Missense Mutation (SNP) | VAF 176/178 reads (99%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV65805881; called by muse, mutect2, varscan2
- CDON | c.3259C>T p.P1087S | Missense Mutation (SNP) | VAF 149/326 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV55004145; called by muse, mutect2
- CDON | c.2446G>A p.V816I | Missense Mutation (SNP) | VAF 154/353 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs1565512568; called by muse, mutect2, varscan2
- CDYL2 | c.772G>A p.E258K | Missense Mutation (SNP) | VAF 158/335 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.41); catalogued as COSV73653844; called by muse, mutect2, varscan2
- CDYL2 | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 231/450 reads (51%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV73647617; called by muse, mutect2, varscan2
- CEACAM18 | c.65C>T p.A22V | Missense Mutation (SNP) | VAF 116/250 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs765730737; called by muse, varscan2
- CELF6 | c.853G>A p.V285I | Missense Mutation (SNP) | VAF 236/511 reads (46%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as rs1227803610; called by muse, mutect2, varscan2
- CEMIP2 | c.895G>A p.E299K | Missense Mutation (SNP) | VAF 200/410 reads (49%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as rs1564022163; called by muse, mutect2, varscan2
- CENPE | c.1687G>A p.V563I | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.05); catalogued as rs1189277464, COSV54386538; called by muse, mutect2, varscan2
- CEP104 | c.1234G>A p.G412S | Missense Mutation (SNP) | VAF 170/359 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.018); catalogued as rs548273305, COSV100986673; called by muse, mutect2, varscan2
- CEP131 | c.1235C>T p.P412L | Missense Mutation (SNP) | VAF 274/577 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs769569324; called by muse, mutect2, varscan2
- CEP192 | c.4933G>A p.A1645T | Missense Mutation (SNP) | VAF 150/335 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs1376185750; called by muse, mutect2, varscan2
- CEP192 | c.7258G>A p.A2420T | Missense Mutation (SNP) | VAF 103/209 reads (49%) | SIFT tolerated (0.11); PolyPhen benign (0.274); catalogued as COSV58066651; called by muse, mutect2, varscan2
- CEP43 | c.926G>A p.R309K | Missense Mutation (SNP) | VAF 100/105 reads (95%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as rs1156678340, COSV100835663; called by muse, mutect2, varscan2
- CEP72 | c.1925G>A p.G642E | Missense Mutation (SNP) | VAF 119/282 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as COSV99374921; called by muse, mutect2, varscan2
- CERKL | c.44G>A p.G15D | Missense Mutation (SNP) | VAF 221/447 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen probably damaging (0.965); catalogued as rs1455481500; called by muse, mutect2, varscan2
- CES2 | c.1138-1G>A p.X380_splice | Splice Site (SNP) | VAF 127/240 reads (53%) | catalogued as rs755778606; called by muse, mutect2, varscan2
- CFAP44 | c.4317G>A p.M1439I | Missense Mutation (SNP) | VAF 64/152 reads (42%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs1450398059; called by muse, mutect2, varscan2
- CFAP61 | c.697G>A p.E233K | Missense Mutation (SNP) | VAF 108/352 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV55647324; called by muse, mutect2, varscan2
- CFAP92 | c.586G>A p.D196N | Missense Mutation (SNP) | VAF 178/368 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs773157291; called by muse, mutect2, varscan2
- CGNL1 | c.1328C>T p.T443I | Missense Mutation (SNP) | VAF 202/440 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs142868083; called by muse, mutect2, varscan2
- CHAF1A | c.2546C>T p.P849L | Missense Mutation (SNP) | VAF 203/426 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.236); catalogued as rs1467990294; called by muse, mutect2, varscan2
- CHD1L | c.1751C>T p.P584L | Missense Mutation (SNP) | VAF 150/292 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV100787453; called by muse, mutect2, varscan2
- CHD3 | c.5969C>T p.P1990L (on ENST00000330494 / NM_001005273.3; = p.P1956L on NM_005852.4) | Missense Mutation (SNP) | VAF 136/305 reads (45%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.018); catalogued as rs1325744232; called by muse, mutect2, varscan2
- CHD6 | c.6679C>T p.P2227S | Missense Mutation (SNP) | VAF 251/702 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.023); catalogued as COSV64692319; called by muse, mutect2, varscan2
- CHD7 | c.1318C>T p.P440S | Missense Mutation (SNP) | VAF 138/276 reads (50%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.212); catalogued as COSV101418385; called by muse, mutect2, varscan2
- CHD9 | c.8582G>A p.S2861N (on ENST00000398510 / NM_001382353.1; = p.S2845N on NM_025134.7) | Missense Mutation (SNP) | VAF 177/345 reads (51%) | SIFT tolerated, low confidence (0.35); PolyPhen probably damaging (0.914); catalogued as rs1379274044; called by muse, mutect2, varscan2
- CHEK2 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 131/131 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.199); catalogued as rs786203977, COSV60428094; ClinVar: uncertain significance / conflicting interpretations of pathogenicity / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- CHGB | c.1081C>T p.R361C | Missense Mutation (SNP) | VAF 172/484 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); catalogued as rs144051265; called by muse, mutect2, varscan2
- CHMP4A | c.181+1G>A p.X61_splice | Splice Site (SNP) | VAF 134/273 reads (49%) | catalogued as rs1473968830; called by muse, mutect2, varscan2
- CHMP7 | c.526C>T p.P176S | Missense Mutation (SNP) | VAF 216/441 reads (49%) | SIFT tolerated (0.69); PolyPhen benign (0.018); catalogued as COSV57533085; called by muse, mutect2, varscan2
- CHODL | c.199G>A p.V67I | Missense Mutation (SNP) | VAF 166/365 reads (45%) | SIFT tolerated (0.25); PolyPhen benign (0.02); catalogued as COSV54732028; called by muse, mutect2, varscan2
- CHPF2 | c.1774C>T p.L592F | Missense Mutation (SNP) | VAF 84/884 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV50389079; called by muse, mutect2
- CHRFAM7A | c.590C>T p.S197F | Missense Mutation (SNP) | VAF 91/329 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761496042; called by muse, mutect2, varscan2
- CHRM2 | c.701G>A p.S234N | Missense Mutation (SNP) | VAF 208/665 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV57786323; called by muse, mutect2, varscan2
- CHRNB1 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 183/432 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1202262413; called by muse, mutect2, varscan2
- CHRNB3 | c.980C>T p.T327M | Missense Mutation (SNP) | VAF 200/442 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs202057288; called by muse, mutect2, varscan2
- CILP2 | c.2278G>A p.V760I | Missense Mutation (SNP) | VAF 335/774 reads (43%) | SIFT tolerated (0.45); PolyPhen benign (0.241); catalogued as COSV52280748; called by muse, mutect2
- CIPC | c.817C>T p.L273F | Missense Mutation (SNP) | VAF 181/386 reads (47%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs200828779; called by muse, mutect2, varscan2
- CLCN1 | c.1312G>A p.G438S | Missense Mutation (SNP) | VAF 208/695 reads (30%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.951); catalogued as rs1476813483; called by muse, mutect2, varscan2
- CLCNKA | c.355G>A p.G119R | Missense Mutation (SNP) | VAF 105/217 reads (48%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as COSV100509802; called by muse, mutect2, varscan2
- CLGN | c.1074G>A p.W358* | Nonsense Mutation (SNP) | VAF 217/419 reads (52%) | catalogued as COSV100346462; called by muse, mutect2, varscan2
- CLMN | c.485G>A p.G162D | Missense Mutation (SNP) | VAF 177/369 reads (48%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.452); catalogued as COSV54182751, COSV54186592; called by muse, mutect2, varscan2
- CLSPN | c.2563G>A p.G855R | Missense Mutation (SNP) | VAF 145/375 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV52049086; called by muse, mutect2, varscan2
- CNPY1 | c.74G>A p.G25E | Missense Mutation (SNP) | VAF 205/720 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.046); catalogued as COSV58788744; called by muse, mutect2, varscan2
- CNTNAP4 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 136/278 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.051); catalogued as rs376166823; called by muse, mutect2, varscan2
- CNTROB | c.1810C>T p.P604S | Missense Mutation (SNP) | VAF 293/576 reads (51%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV66609579; called by muse, mutect2
- COL11A2 | c.3542C>T p.P1181L (on ENST00000341947 / NM_080680.3; = p.P1074L on NM_080679.2) | Missense Mutation (SNP) | VAF 213/420 reads (51%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as rs776744859; called by muse, mutect2, varscan2
- COL12A1 | c.9071G>C p.G3024A | Missense Mutation (SNP) | VAF 228/451 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV59401173; called by muse, mutect2, varscan2
- COL16A1 | c.2282C>T p.P761L | Missense Mutation (SNP) | VAF 194/415 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as COSV99057207; called by muse, mutect2, varscan2
- COL1A1 | c.3554C>T p.P1185L | Missense Mutation (SNP) | VAF 257/527 reads (49%) | SIFT tolerated (0.24); PolyPhen benign (0.001); catalogued as COSV56803590; called by muse, mutect2, varscan2
- COL1A2 | c.2119C>T p.P707S | Missense Mutation (SNP) | VAF 172/632 reads (27%) | SIFT tolerated (0.57); PolyPhen benign (0.197); catalogued as COSV99800455; called by muse, mutect2, varscan2
- COL1A2 | c.3554G>A p.G1185E | Missense Mutation (SNP) | VAF 56/525 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766941490; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- COL24A1 | c.37G>A p.V13I | Missense Mutation (SNP) | VAF 155/327 reads (47%) | SIFT tolerated (0.33); PolyPhen benign (0.108); catalogued as rs985049925; called by muse, mutect2, varscan2
- COL6A1 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 138/318 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.997); catalogued as rs540429266; called by muse, mutect2, varscan2
- COL6A2 | c.3038G>A p.R1013H | Missense Mutation (SNP) | VAF 126/278 reads (45%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.986); catalogued as rs751512548, COSV52428126; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL6A3 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 142/297 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.776); catalogued as rs1345492472; called by muse, mutect2, varscan2
- COL7A1 | c.5635G>A p.A1879T | Missense Mutation (SNP) | VAF 196/395 reads (50%) | SIFT tolerated (0.57); PolyPhen possibly damaging (0.607); catalogued as rs920461757; called by muse, mutect2, varscan2
- COL9A1 | c.985G>A p.G329R | Missense Mutation (SNP) | VAF 147/295 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1368487943, COSV57888050; called by muse, mutect2, varscan2
- COLQ | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 185/361 reads (51%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.622); catalogued as rs1183515679, COSV101082590; called by muse, mutect2, varscan2
- COPA | c.643C>T p.P215S | Missense Mutation (SNP) | VAF 112/246 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV54100783; called by muse, mutect2, varscan2
- CP | c.2389G>A p.E797K | Missense Mutation (SNP) | VAF 127/279 reads (46%) | SIFT tolerated (0.77); PolyPhen benign (0.007); catalogued as CD962774; called by muse, mutect2, varscan2
- CPA1 | c.674G>A p.G225D | Missense Mutation (SNP) | VAF 113/469 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99163344; called by muse, mutect2, varscan2
- CPA3 | c.920C>T p.S307F | Missense Mutation (SNP) | VAF 141/303 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56044943; called by muse, mutect2, varscan2
- CPLANE1 | c.9065G>A p.G3022E | Missense Mutation (SNP) | VAF 88/198 reads (44%) | SIFT tolerated (0.38); PolyPhen benign (0.027); catalogued as rs376064818; called by muse, mutect2, varscan2
- CPS1 | c.2320C>T p.P774S | Missense Mutation (SNP) | VAF 179/358 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51808896; called by muse, mutect2, varscan2
- CR1 | c.3395G>A p.C1132Y | Missense Mutation (SNP) | VAF 197/481 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs747336966; called by muse, mutect2, varscan2
- CRACDL | c.1331C>T p.P444L | Missense Mutation (SNP) | VAF 280/563 reads (50%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as rs768234946; called by muse, varscan2
- CROCC2 | c.671C>T p.P224L | Missense Mutation (SNP) | VAF 221/442 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs1200072623; called by muse, mutect2, varscan2
- CRTC3 | c.74G>A p.R25K | Missense Mutation (SNP) | VAF 175/369 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.036); catalogued as rs766247155; called by muse, mutect2, varscan2
- CSMD2 | c.8485+1G>A p.X2829_splice | Splice Site (SNP) | VAF 141/266 reads (53%) | catalogued as rs1236056604, COSV53922824, COSV99587535; called by muse, mutect2, varscan2
- CSMD3 | c.3671G>A p.G1224D (on ENST00000297405 / NM_001363185.1; = p.G1120D on NM_052900.3) | Missense Mutation (SNP) | VAF 136/278 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52214401; called by muse, mutect2, varscan2
- CSPG4 | c.5315C>T p.P1772L | Missense Mutation (SNP) | VAF 237/517 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.652); catalogued as rs1215303032; called by muse, mutect2, varscan2
- CTC1 | c.2729C>T p.P910L | Missense Mutation (SNP) | VAF 135/293 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); catalogued as rs532454635; called by muse, mutect2, varscan2
- CTC1 | c.897G>A p.W299* | Nonsense Mutation (SNP) | VAF 209/415 reads (50%) | catalogued as rs1377355470; called by muse, mutect2, varscan2
- CTC1 | c.34G>A p.E12K | Missense Mutation (SNP) | VAF 120/242 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs752218784; called by muse, mutect2, varscan2
- CTDP1 | c.2854G>A p.A952T | Missense Mutation (SNP) | VAF 159/364 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1343959902; called by muse, mutect2, varscan2
- CTNNA2 | c.583C>T p.Q195* | Nonsense Mutation (SNP) | VAF 106/207 reads (51%) | catalogued as COSV63575561, COSV63585566; called by muse, mutect2, varscan2
- CTNNA3 | c.1052G>A p.G351E | Missense Mutation (SNP) | VAF 87/89 reads (98%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65562416, COSV65609223; called by muse, mutect2, varscan2
- CTNND2 | c.2080G>A p.E694K | Missense Mutation (SNP) | VAF 178/340 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.078); catalogued as COSV58879027; called by muse, mutect2, varscan2
- CTTNBP2 | c.3560C>T p.S1187F | Missense Mutation (SNP) | VAF 100/363 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.007); catalogued as COSV99353805; called by muse, mutect2, varscan2
- CUBN | c.9214G>A p.D3072N | Missense Mutation (SNP) | VAF 137/139 reads (99%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs371144749, COSV100912275; called by muse, mutect2, varscan2
- CUEDC1 | c.580G>A p.D194N | Missense Mutation (SNP) | VAF 117/250 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0.159); catalogued as COSV64226560; called by muse, mutect2, varscan2
- CUL1 | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 44/586 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1239708834, COSV57392398; called by muse, mutect2
- CXCR6 | c.319G>A p.G107S | Missense Mutation (SNP) | VAF 168/326 reads (52%) | SIFT tolerated (0.2); PolyPhen benign (0.229); catalogued as COSV56115107; called by muse, mutect2, varscan2
- CYLC1 | c.304C>T p.H102Y | Missense Mutation (SNP) | VAF 182/372 reads (49%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as COSV61413593; called by muse, mutect2, varscan2
- CYP11B1 | c.587C>T p.T196I | Missense Mutation (SNP) | VAF 211/440 reads (48%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.954); catalogued as COSV99455775; called by muse, mutect2, varscan2
- CYP27A1 | c.1078G>A p.A360T | Missense Mutation (SNP) | VAF 170/402 reads (42%) | SIFT tolerated (0.49); PolyPhen benign (0.241); catalogued as rs1463950337; called by muse, varscan2
- CYP27A1 | c.1174G>A p.E392K | Missense Mutation (SNP) | VAF 128/298 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1553616443; ClinVar: uncertain significance; called by muse, varscan2
- CYP27B1 | c.856G>A p.D286N | Missense Mutation (SNP) | VAF 225/531 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0.216); catalogued as rs772608705; called by muse, mutect2, varscan2
- CYP4B1 | c.742C>T p.R248W | Missense Mutation (SNP) | VAF 168/364 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs770487913; called by muse, varscan2
- CYP7B1 | c.1018C>T p.H340Y | Missense Mutation (SNP) | VAF 132/298 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.005); catalogued as rs757698965; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DAPK1 | c.325G>A p.E109K | Missense Mutation (SNP) | VAF 144/314 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.015); catalogued as rs769267771, COSV63792861; called by muse, mutect2, varscan2
- DCBLD1 | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 114/355 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.844); catalogued as COSV51647306; called by muse, mutect2, varscan2
- DCLK2 | c.1733G>A p.G578D | Missense Mutation (SNP) | VAF 125/307 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs905696183, COSV56210380; called by muse, mutect2, varscan2
- DCST1 | c.1067G>A p.S356N | Missense Mutation (SNP) | VAF 217/459 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.042); catalogued as rs199543135; called by muse, varscan2
- DCSTAMP | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 155/318 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99886873; called by muse, mutect2, varscan2
- DENND11 | c.85G>A p.A29T | Missense Mutation (SNP) | VAF 132/340 reads (39%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.005); catalogued as rs1271535486; called by muse, mutect2, varscan2
- DHH | c.715G>A p.V239M | Missense Mutation (SNP) | VAF 424/748 reads (57%) | SIFT deleterious (0.01); PolyPhen benign (0.104); catalogued as rs1293421009; called by muse, mutect2, varscan2
- DHX38 | c.1635C>T p.I545= | Splice Region (SNP) | VAF 142/312 reads (46%) | catalogued as rs1472854146; called by muse, mutect2, varscan2
- DISP3 | c.2263C>T p.R755W | Missense Mutation (SNP) | VAF 274/560 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs764393813, COSV53820716; called by muse, mutect2, varscan2
- DIXDC1 | c.1240G>A p.D414N (on ENST00000440460 / NM_001037954.4; = p.D203N on NM_033425.4) | Missense Mutation (SNP) | VAF 145/316 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs782668131; called by muse, mutect2, varscan2
- DLG1 | c.902C>T p.S301F | Missense Mutation (SNP) | VAF 145/321 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV58377107; called by muse, mutect2, varscan2
- DLG2 | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 182/397 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs1329785466, COSV54636483; called by muse, mutect2, varscan2
- DLL1 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 318/626 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.251); catalogued as rs1477195165; called by muse, mutect2, varscan2
- DMD | c.7411G>A p.A2471T | Missense Mutation (SNP) | VAF 201/432 reads (47%) | SIFT tolerated (0.09); PolyPhen benign (0.316); catalogued as COSV58908190; called by muse, mutect2, varscan2
- DMGDH | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 225/443 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV54864832; called by muse, mutect2, varscan2
- DMWD | c.1880C>T p.T627I | Missense Mutation (SNP) | VAF 131/275 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as COSV99060367; called by muse, mutect2, varscan2
- DNAH1 | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 111/303 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV70227981; called by muse, mutect2, varscan2
- DNAH10 | c.10409G>A p.G3470E (on ENST00000409039; = p.G3409E on NM_207437.3) | Missense Mutation (SNP) | VAF 188/400 reads (47%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.516); catalogued as COSV68999963; called by muse, varscan2
- DNAH2 | c.1516C>T p.R506W | Missense Mutation (SNP) | VAF 98/188 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.832); catalogued as rs527569928; called by muse, varscan2
- DNAH7 | c.10795G>A p.G3599R | Missense Mutation (SNP) | VAF 216/453 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56764327; called by muse, mutect2, varscan2
- DNAH8 | c.1103G>A p.R368K | Missense Mutation (SNP) | VAF 72/156 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.868); catalogued as rs780507357; called by muse, mutect2, varscan2
- DNAH9 | c.6296C>T p.P2099L | Missense Mutation (SNP) | VAF 197/460 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs768380502; called by muse, mutect2
- DOC2B | c.134C>T p.P45L | Missense Mutation (SNP) | VAF 289/548 reads (53%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs1269002728; called by muse, mutect2, varscan2
- DPEP2 | c.1255G>A p.D419N | Missense Mutation (SNP) | VAF 183/375 reads (49%) | SIFT tolerated (0.38); PolyPhen benign (0.018); catalogued as rs746971748; called by muse, mutect2, varscan2
- DPEP3 | c.617C>T p.S206F | Missense Mutation (SNP) | VAF 213/460 reads (46%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.738); catalogued as rs1456389727, COSV52051982; called by muse, mutect2, varscan2
- DPP3 | c.1702C>T p.H568Y | Missense Mutation (SNP) | VAF 144/294 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100855413; called by muse, mutect2, varscan2
- DPP9 | c.1064C>T p.A355V (on ENST00000598800; = p.A384V on NM_139159.5) | Missense Mutation (SNP) | VAF 126/321 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.06); catalogued as COSV53591108; called by muse, mutect2, varscan2
- DSG1 | c.599G>A p.R200K | Missense Mutation (SNP) | VAF 114/237 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.029); catalogued as COSV57138452; called by muse, mutect2, varscan2
- DSG1 | c.2474C>T p.P825L | Missense Mutation (SNP) | VAF 197/365 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.086); catalogued as COSV57135557; called by muse, mutect2, varscan2
- DSP | c.4432G>A p.D1478N | Missense Mutation (SNP) | VAF 123/270 reads (46%) | SIFT tolerated (0.05); PolyPhen benign (0.343); catalogued as rs923482634; called by muse, mutect2, varscan2
- DSP | c.6017C>T p.S2006F | Missense Mutation (SNP) | VAF 239/449 reads (53%) | SIFT deleterious (0.04); PolyPhen benign (0.276); catalogued as COSV65794259; called by muse, mutect2, varscan2
- DSPP | c.3629G>A p.S1210N | Missense Mutation (SNP) | VAF 179/399 reads (45%) | SIFT tolerated, low confidence (0.1); PolyPhen possibly damaging (0.877); catalogued as COSV56810228; called by muse, mutect2, varscan2
- DST | c.13276C>T p.P4426S (on ENST00000361203 / NM_001374722.1; = p.P2014S on NM_015548.5) | Missense Mutation (SNP) | VAF 88/183 reads (48%) | SIFT tolerated (0.2); PolyPhen benign (0.062); catalogued as rs1233835439; called by muse, mutect2, varscan2
- DTX4 | c.1679G>A p.G560D | Missense Mutation (SNP) | VAF 185/360 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1459549384, COSV57093319; called by muse, mutect2, varscan2
- DUOXA1 | c.487C>T p.P163S | Missense Mutation (SNP) | VAF 215/451 reads (48%) | SIFT tolerated (0.39); PolyPhen benign (0.158); catalogued as COSV50994263; called by muse, mutect2, varscan2
- DUSP9 | c.1096C>T p.P366S | Missense Mutation (SNP) | VAF 286/652 reads (44%) | SIFT tolerated (0.35); PolyPhen benign (0.186); catalogued as COSV61437972, COSV61438587; called by muse, varscan2
- DYNC1H1 | c.10978G>A p.V3660M | Missense Mutation (SNP) | VAF 227/475 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1199669093; called by muse, mutect2, varscan2
- DZIP1L | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 163/333 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.722); catalogued as rs752865093; called by muse, mutect2, varscan2
- EBF3 | c.812G>A p.S271N (on ENST00000355311 / NM_001375392.1; = p.S262N on NM_001005463.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 167/167 reads (100%) | SIFT tolerated (0.15); PolyPhen benign (0.073); catalogued as COSV62480712; called by muse, mutect2, varscan2
- EDEM2 | c.1487G>A p.W496* | Nonsense Mutation (SNP) | VAF 219/658 reads (33%) | catalogued as rs1210258111; called by muse, mutect2, varscan2
- EFCAB11 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 121/282 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.768); catalogued as rs535924013; called by muse, mutect2, varscan2
- EFCAB6 | c.3977G>A p.R1326H | Missense Mutation (SNP) | VAF 237/237 reads (100%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.982); catalogued as rs749917338, COSV53067194; called by muse, mutect2, varscan2
- EGF | c.2175G>A p.M725I | Missense Mutation (SNP) | VAF 160/312 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.197); catalogued as COSV99490708; called by muse, mutect2, varscan2
- EIF5A | c.452C>T p.A151V | Missense Mutation (SNP) | VAF 139/329 reads (42%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV59746816; called by muse, mutect2, varscan2
- ELAC2 | c.1838G>A p.G613E | Missense Mutation (SNP) | VAF 232/469 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.669); catalogued as rs1274955415; called by muse, mutect2
- ELF3 | c.296G>A p.G99D | Missense Mutation (SNP) | VAF 194/403 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62837304; called by muse, mutect2, varscan2
- ELMOD3 | c.214G>A p.V72M | Missense Mutation (SNP) | VAF 140/276 reads (51%) | SIFT tolerated (0.13); PolyPhen benign (0.009); catalogued as rs1049052744; called by muse, mutect2, varscan2
- EME2 | c.25G>A p.A9T | Missense Mutation (SNP) | VAF 139/305 reads (46%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0.049); catalogued as rs1387846643, COSV51600943; called by muse, mutect2, varscan2
- EML5 | c.4954G>A p.A1652T (on ENST00000380664; = p.A1660T on NM_183387.3) | Missense Mutation (SNP) | VAF 190/355 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as rs1371636301; called by muse, mutect2, varscan2
- EML6 | c.4117G>T p.G1373C | Missense Mutation (SNP) | VAF 43/334 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62873746; called by muse, mutect2, varscan2
- ENPP2 | c.854G>A p.R285K | Missense Mutation (SNP) | VAF 168/363 reads (46%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV50012152; called by muse, mutect2, varscan2
- EPB41L4B | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 186/388 reads (48%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.76); catalogued as COSV63124285; called by muse, mutect2, varscan2
- EPHA10 | c.529G>A p.V177M | Missense Mutation (SNP) | VAF 294/632 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs1175198331; called by muse, mutect2
- EPHX3 | c.684G>A p.W228* | Nonsense Mutation (SNP) | VAF 101/218 reads (46%) | catalogued as rs748545958; called by muse, mutect2, varscan2
- EPS15L1 | c.2366C>T p.P789L | Missense Mutation (SNP) | VAF 106/238 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1568399426; called by muse, mutect2, varscan2
- ERICH6 | c.1472C>T p.S491F | Missense Mutation (SNP) | VAF 128/278 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.062); catalogued as rs1255099858; called by muse, mutect2, varscan2
- ERLIN2 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 110/259 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs1392269878; called by muse, mutect2, varscan2
- ERN2 | c.238G>A p.A80T | Missense Mutation (SNP) | VAF 94/217 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.015); catalogued as rs1452799859; called by muse, mutect2, varscan2
- ETFBKMT | c.218C>T p.T73I | Missense Mutation (SNP) | VAF 204/488 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139707287; called by muse, mutect2, varscan2
- ETV1 | c.661C>T p.P221S | Missense Mutation (SNP) | VAF 42/478 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.217); catalogued as rs781034658, COSV54145886, COSV99623216; called by muse, mutect2
- ETV7 | c.652G>A p.G218S | Missense Mutation (SNP) | VAF 137/294 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as rs1045475179, COSV60317199; called by muse, mutect2, varscan2
- EXOC8 | c.461G>A p.G154D | Missense Mutation (SNP) | VAF 274/544 reads (50%) | SIFT tolerated (0.47); PolyPhen benign (0.01); catalogued as rs756875462; called by muse, mutect2, varscan2
- EYS | c.1901G>C p.R634T | Missense Mutation (SNP) | VAF 60/398 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as COSV101005066, COSV65459008, COSV65459327; called by muse, mutect2, varscan2
- F11R | c.805A>G p.T269A | Missense Mutation (SNP) | VAF 169/331 reads (51%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs150177570; called by muse, mutect2
- F12 | c.1253C>T p.P418L | Missense Mutation (SNP) | VAF 175/363 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs770910748; called by muse, mutect2, varscan2
- F2 | c.625C>T p.P209S | Missense Mutation (SNP) | VAF 181/384 reads (47%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as COSV61317493; called by muse, mutect2, varscan2
- FADS6 | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 126/272 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.961); catalogued as rs367664659, COSV100044211; called by muse, varscan2
- FAM131B | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 108/444 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1231345359, COSV58374340; called by muse, mutect2, varscan2
- FAM131B | c.763G>A p.G255R | Missense Mutation (SNP) | VAF 223/768 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs761262315; called by muse, mutect2, varscan2
- FAM135B | c.2659G>A p.A887T | Missense Mutation (SNP) | VAF 204/415 reads (49%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.003); catalogued as rs1369488257, COSV52721958; called by muse, mutect2, varscan2
- FAM135B | c.2294C>T p.T765I | Missense Mutation (SNP) | VAF 174/386 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as rs1339738800, COSV52757001; called by muse, mutect2, varscan2
- FAM184B | c.1600C>T p.P534S | Missense Mutation (SNP) | VAF 79/194 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.046); catalogued as COSV53953703; called by muse, mutect2, varscan2
- FAM214B | c.398C>T p.T133I | Missense Mutation (SNP) | VAF 234/234 reads (100%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); catalogued as rs1259433114; called by muse, mutect2, varscan2
- FAM3C | c.656A>G p.E219G | Missense Mutation (SNP) | VAF 36/395 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.029); catalogued as rs1390611714; called by muse, mutect2, varscan2
- FAM43B | c.712C>T p.R238C | Missense Mutation (SNP) | VAF 266/571 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753182171; called by muse, varscan2
- FAM47B | c.1267C>T p.L423F | Missense Mutation (SNP) | VAF 227/490 reads (46%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.942); catalogued as rs756181314; called by muse, mutect2, varscan2
- FAM50A | c.202G>A p.V68M | Missense Mutation (SNP) | VAF 252/479 reads (53%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as rs782164633; called by muse, mutect2, varscan2
- FAM53A | c.719G>A p.S240N | Missense Mutation (SNP) | VAF 273/548 reads (50%) | SIFT tolerated (0.39); PolyPhen benign (0.038); catalogued as rs373128003; called by muse, mutect2, varscan2
- FAM83H | c.1469C>T p.T490I | Missense Mutation (SNP) | VAF 368/735 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs782767148; called by muse, mutect2, varscan2
- FAM89A | c.272C>T p.A91V | Missense Mutation (SNP) | VAF 58/365 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.102); catalogued as rs1382328668; called by muse, mutect2, varscan2
- FANCL | c.369G>A p.W123* | Nonsense Mutation (SNP) | VAF 73/212 reads (34%) | catalogued as rs1386476396; called by muse, mutect2, varscan2
- FAT1 | c.4615G>A p.V1539M | Missense Mutation (SNP) | VAF 125/264 reads (47%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.954); catalogued as rs1284325295; called by muse, mutect2, varscan2
- FAT2 | c.9799G>A p.D3267N | Missense Mutation (SNP) | VAF 154/285 reads (54%) | SIFT tolerated (0.36); PolyPhen benign (0.031); catalogued as rs1485626092; called by muse, mutect2, varscan2
- FAT2 | c.9067G>A p.D3023N | Missense Mutation (SNP) | VAF 142/294 reads (48%) | SIFT tolerated (0.28); PolyPhen benign (0.165); catalogued as COSV55818998; called by muse, mutect2, varscan2
- FAT2 | c.209G>A p.R70K | Missense Mutation (SNP) | VAF 168/348 reads (48%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as rs1199210774, COSV55827025; called by muse, mutect2, varscan2
- FAT3 | c.9674C>T p.T3225I | Missense Mutation (SNP) | VAF 150/323 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.688); catalogued as COSV53085376; called by muse, mutect2, varscan2
- FBN3 | c.130C>T p.R44C | Missense Mutation (SNP) | VAF 238/516 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs752049859; called by muse, mutect2, varscan2
- FBXL18 | c.1261C>T p.P421S | Missense Mutation (SNP) | VAF 297/764 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs754592673; called by muse, mutect2, varscan2
- FBXO33 | c.1507G>A p.A503T | Missense Mutation (SNP) | VAF 175/422 reads (41%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); catalogued as rs1434264312; called by muse, mutect2, varscan2
- FCAR | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 237/487 reads (49%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.734); catalogued as rs1387628789; called by muse, mutect2, varscan2
- FCN1 | c.637G>A p.G213S | Missense Mutation (SNP) | VAF 126/273 reads (46%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as rs774154168; called by muse, mutect2, varscan2
- FCN3 | c.455C>T p.A152V | Missense Mutation (SNP) | VAF 154/335 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.239); catalogued as rs1439948169; called by muse, mutect2, varscan2
- FCRL4 | c.271C>T p.P91S | Missense Mutation (SNP) | VAF 176/352 reads (50%) | SIFT tolerated (0.91); PolyPhen benign (0.017); catalogued as rs1214822489, COSV99619249; called by muse, mutect2, varscan2
- FERMT1 | c.1225C>T p.L409F | Missense Mutation (SNP) | VAF 52/236 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as rs768269556; called by muse, mutect2, varscan2
- FGD6 | c.3422G>A p.R1141K | Missense Mutation (SNP) | VAF 95/311 reads (31%) | SIFT tolerated (0.27); PolyPhen benign (0.015); catalogued as rs759581247; called by muse, mutect2, varscan2
- FGF3 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 325/622 reads (52%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.015); catalogued as COSV61926275; called by muse, mutect2, varscan2
- FGF8 | c.277G>A p.A93T (on ENST00000344255 / NM_033164.4; = p.A75T on NM_006119.6) | Missense Mutation (SNP) | VAF 159/159 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV60142133; called by muse, mutect2, varscan2
- FIBCD1 | c.716C>T p.S239F | Missense Mutation (SNP) | VAF 154/310 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.24); catalogued as rs1161084829; called by muse, mutect2, varscan2
- FLG | c.9908G>A p.G3303E | Missense Mutation (SNP) | VAF 257/565 reads (45%) | SIFT tolerated (0.25); PolyPhen probably damaging (1); catalogued as COSV64246240; called by muse, mutect2, varscan2
- FLRT2 | c.1135C>T p.P379S | Missense Mutation (SNP) | VAF 250/482 reads (52%) | SIFT tolerated (0.9); PolyPhen benign (0.291); catalogued as rs747429440; called by muse, mutect2, varscan2
- FNDC1 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 186/397 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs372511186; called by muse, mutect2, varscan2
- FOLR1 | c.655G>A p.G219S | Missense Mutation (SNP) | VAF 215/456 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.542); catalogued as COSV56616088; called by muse, mutect2, varscan2
- FOXA1 | c.335G>A p.G112D | Missense Mutation (SNP) | VAF 358/666 reads (54%) | SIFT tolerated (0.43); PolyPhen benign (0.419); catalogued as COSV99163573; called by muse, mutect2, varscan2
- FOXP1 | c.911G>A p.G304E | Missense Mutation (SNP) | VAF 127/251 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.778); catalogued as COSV59549126; called by muse, mutect2, varscan2
- FRAS1 | c.11566G>A p.V3856I | Missense Mutation (SNP) | VAF 176/357 reads (49%) | SIFT tolerated (0.09); PolyPhen benign (0.015); catalogued as rs369258214; called by muse, mutect2, varscan2
- FREM1 | c.1018C>T p.P340S | Missense Mutation (SNP) | VAF 207/409 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs753189419, COSV100772202; called by muse, mutect2, varscan2
- FRMD3 | c.670C>T p.P224S | Missense Mutation (SNP) | VAF 73/172 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs750964503, COSV58466691; called by muse, mutect2, varscan2
- FRMD3 | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 137/315 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.616); catalogued as rs769838552; called by muse, mutect2, varscan2
- FRY | c.1281G>A p.Q427= | Splice Region (SNP) | VAF 72/140 reads (51%) | catalogued as rs371328946; called by muse, mutect2, varscan2
- FSCN3 | c.1037G>A p.G346D | Missense Mutation (SNP) | VAF 81/735 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.077); catalogued as COSV56171092; called by muse, mutect2, varscan2
- FSHB | c.39G>A p.W13* | Nonsense Mutation (SNP) | VAF 130/269 reads (48%) | catalogued as rs764046593, COSV54223139; called by muse, mutect2, varscan2
- FSTL1 | c.526G>A p.E176K | Missense Mutation (SNP) | VAF 182/340 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV55233776; called by muse, mutect2, varscan2
- FSTL5 | c.1976G>A p.G659D | Missense Mutation (SNP) | VAF 38/309 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60209307; called by muse, mutect2, varscan2
- FUBP1 | c.1564C>T p.P522S | Missense Mutation (SNP) | VAF 128/247 reads (52%) | SIFT tolerated (0.72); PolyPhen benign (0.007); catalogued as COSV53934420, COSV53935551; called by muse, mutect2, varscan2
- FYB2 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 135/290 reads (47%) | SIFT tolerated (0.75); PolyPhen benign (0.037); catalogued as rs751789084; called by muse, mutect2, varscan2
- FYN | c.799C>T p.P267S | Missense Mutation (SNP) | VAF 146/335 reads (44%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as COSV57614547; called by muse, mutect2, varscan2
- GALC | c.865G>A p.G289S | Missense Mutation (SNP) | VAF 157/357 reads (44%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs745376018; called by muse, mutect2, varscan2
- GALNT17 | c.106G>A p.G36R | Missense Mutation (SNP) | VAF 225/819 reads (27%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.302); catalogued as rs1357474108, COSV61171297, COSV61178418; called by muse, mutect2, varscan2
- GAS7 | c.977G>A p.R326H (on ENST00000432992 / NM_201433.2; = p.R186H on NM_003644.3) | Missense Mutation (SNP) | VAF 192/386 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV60442605; called by muse, mutect2, varscan2
- GATA2 | c.1280C>T p.P427L | Missense Mutation (SNP) | VAF 281/588 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV100351489; called by muse, mutect2, varscan2
- GATA6 | c.584G>A p.G195D | Missense Mutation (SNP) | VAF 242/501 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.165); catalogued as COSV52525122; called by muse, mutect2, varscan2
- GATAD2A | c.1837C>T p.Q613* | Nonsense Mutation (SNP) | VAF 184/424 reads (43%) | catalogued as COSV53076439; called by muse, mutect2, varscan2
- GCNT3 | c.215G>A p.G72E | Missense Mutation (SNP) | VAF 148/280 reads (53%) | SIFT tolerated (0.13); PolyPhen benign (0.086); catalogued as rs1043381966; called by muse, varscan2
- GDPD4 | c.526C>T p.L176F | Missense Mutation (SNP) | VAF 143/273 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV60017026; called by muse, mutect2, varscan2
- GIMAP8 | c.491G>A p.R164Q | Missense Mutation (SNP) | VAF 167/544 reads (31%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.506); catalogued as rs756123094, COSV56229483, COSV56232886; called by muse, mutect2, varscan2
- GIT1 | c.829G>A p.E277K | Missense Mutation (SNP) | VAF 152/373 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV56611191; called by muse, mutect2, varscan2
- GJA3 | c.118G>A p.A40T | Missense Mutation (SNP) | VAF 219/478 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs762450453, COSV53836120; called by muse, mutect2, varscan2
- GJB5 | c.298G>A p.V100I | Missense Mutation (SNP) | VAF 214/422 reads (51%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs924945971; called by muse, mutect2, varscan2
- GKN1 | c.307G>A p.E103K | Missense Mutation (SNP) | VAF 144/295 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0.125); catalogued as rs756122878; called by muse, mutect2, varscan2
- GLI3 | c.4352G>A p.S1451N | Missense Mutation (SNP) | VAF 211/478 reads (44%) | SIFT tolerated (0.46); PolyPhen benign (0.075); catalogued as rs374978412; called by muse, mutect2, varscan2
- GLIS1 | c.772G>A p.G258S | Missense Mutation (SNP) | VAF 139/294 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100391071, COSV56552296; called by muse, mutect2, varscan2
- GLOD5 | c.439C>T p.P147S | Missense Mutation (SNP) | VAF 180/408 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57489248; called by muse, mutect2, varscan2
- GLP2R | c.926C>T p.A309V | Missense Mutation (SNP) | VAF 104/238 reads (44%) | SIFT tolerated (0.29); PolyPhen benign (0.098); catalogued as COSV52325275; called by muse, varscan2
- GLT1D1 | c.808G>A p.A270T (on ENST00000442111 / NM_001366889.1; = p.A190T on NM_144669.3) | Missense Mutation (SNP) | VAF 101/229 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1351874472; called by muse, mutect2, varscan2
- GMIP | c.2770C>T p.P924S | Missense Mutation (SNP) | VAF 299/631 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.115); catalogued as rs1427639018; called by muse, mutect2, varscan2
- GNA14 | c.847C>T p.H283Y | Missense Mutation (SNP) | VAF 106/237 reads (45%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.972); catalogued as rs772468318; called by muse, mutect2, varscan2
- GNAT3 | c.118G>A p.G40R | Missense Mutation (SNP) | VAF 103/327 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs745305676, COSV101242421; called by muse, mutect2, varscan2
- GNG4 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 130/241 reads (54%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.484); catalogued as rs1372374720; called by muse, mutect2
- GNG8 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 196/415 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs1474469293; called by muse, mutect2, varscan2
- GOLGA2 | c.1756G>A p.V586M | Missense Mutation (SNP) | VAF 111/220 reads (50%) | SIFT tolerated (0.14); PolyPhen benign (0.116); catalogued as rs766292407; called by muse, mutect2, varscan2
- GON4L | c.4940G>A p.G1647D | Missense Mutation (SNP) | VAF 121/239 reads (51%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1389470377; called by muse, mutect2, varscan2
- GPD2 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 194/390 reads (50%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as COSV60096458; called by muse, mutect2, varscan2
- GPR149 | c.1708C>T p.L570F | Missense Mutation (SNP) | VAF 112/226 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67667066; called by muse, mutect2, varscan2
- GPR3 | c.85G>A p.G29R | Missense Mutation (SNP) | VAF 283/546 reads (52%) | SIFT tolerated (0.56); PolyPhen benign (0.034); catalogued as COSV64994442; called by muse, mutect2, varscan2
- GPR3 | c.155C>T p.T52I | Missense Mutation (SNP) | VAF 248/582 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs536093601; called by muse, mutect2, varscan2
- GPR85 | c.184C>T p.L62F | Missense Mutation (SNP) | VAF 187/683 reads (27%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV51783432; called by muse, mutect2, varscan2
- GPR85 | c.95G>A p.G32E | Missense Mutation (SNP) | VAF 178/692 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.424); catalogued as COSV51785016; called by muse, mutect2
- GPS1 | c.1301C>T p.T434I | Missense Mutation (SNP) | VAF 207/421 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as rs1416432884; called by muse, mutect2, varscan2
- GPT2 | c.1025G>A p.G342D | Missense Mutation (SNP) | VAF 151/299 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60839896; called by muse, mutect2, varscan2
- GREB1 | c.3479C>T p.S1160L | Missense Mutation (SNP) | VAF 214/425 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.285); catalogued as rs773564841; called by muse, mutect2, varscan2
- GREB1 | c.4564C>T p.P1522S | Missense Mutation (SNP) | VAF 181/343 reads (53%) | SIFT tolerated (0.23); PolyPhen benign (0.237); catalogued as rs1263514079; called by muse, mutect2, varscan2
- GRM8 | c.116C>T p.S39F | Missense Mutation (SNP) | VAF 214/765 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs559451048; called by muse, mutect2, varscan2
- GRSF1 | c.233G>A p.G78E | Missense Mutation (SNP) | VAF 174/370 reads (47%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.578); catalogued as rs113167518; called by muse, mutect2, varscan2
- GSDMD | c.1235G>A p.S412N | Missense Mutation (SNP) | VAF 232/470 reads (49%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.999); catalogued as rs1161252300; called by muse, mutect2, varscan2
- GSTA3 | c.248G>A p.G83E | Missense Mutation (SNP) | VAF 105/293 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.653); catalogued as COSV52980302; called by muse, mutect2
- GSTK1 | c.460G>A p.G154R | Missense Mutation (SNP) | VAF 146/520 reads (28%) | SIFT tolerated (0.31); PolyPhen benign (0.057); catalogued as rs1303234079; called by muse, varscan2
- GTF3C1 | c.3908C>T p.A1303V | Missense Mutation (SNP) | VAF 164/377 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.549); catalogued as COSV62241621; called by muse, mutect2, varscan2
- GTF3C3 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 88/195 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); catalogued as COSV55831975; called by muse, mutect2, varscan2
- GUCA2B | c.328G>A p.G110S | Missense Mutation (SNP) | VAF 181/344 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs148141677; called by muse, mutect2, varscan2
- GXYLT2 | c.1219C>T p.H407Y | Missense Mutation (SNP) | VAF 224/460 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); catalogued as rs755794706; called by muse, mutect2, varscan2
- H2BC18 | c.352G>A p.A118T | Missense Mutation (SNP) | VAF 116/283 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.999); catalogued as rs1553754510; called by muse, mutect2, varscan2
- HCFC1 | c.2143C>T p.P715S | Missense Mutation (SNP) | VAF 177/401 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.607); catalogued as COSV60076856; called by muse, mutect2, varscan2
- HDAC3 | c.484C>T p.P162S | Missense Mutation (SNP) | VAF 151/297 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.874); catalogued as rs1228337830; called by muse, mutect2, varscan2
- HECW1 | c.1883C>T p.A628V | Missense Mutation (SNP) | VAF 216/592 reads (36%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0); catalogued as rs760610281; called by muse, mutect2, varscan2
- HECW2 | c.2194G>A p.E732K | Missense Mutation (SNP) | VAF 238/524 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.011); catalogued as COSV53670855; called by muse, mutect2, varscan2
- HEG1 | c.3754G>A p.V1252M | Missense Mutation (SNP) | VAF 152/310 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1488290628; called by muse, mutect2, varscan2
- HEG1 | c.3154C>T p.P1052S | Missense Mutation (SNP) | VAF 133/255 reads (52%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.953); catalogued as rs1288805636; called by muse, mutect2, varscan2
- HELZ2 | c.4714G>A p.D1572N (on ENST00000467148 / NM_001037335.2; = p.D1003N on NM_033405.3) | Missense Mutation (SNP) | VAF 240/746 reads (32%) | SIFT tolerated (0.91); PolyPhen benign (0.022); catalogued as rs1244890938; called by muse, mutect2, varscan2
- HEPH | c.1459G>A p.V487I (on ENST00000343002; = p.V220I on NM_014799.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 207/362 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as rs1438318678; called by muse, mutect2, varscan2
- HGFAC | c.899C>T p.T300I | Missense Mutation (SNP) | VAF 218/464 reads (47%) | SIFT deleterious (0.01); PolyPhen benign (0.42); catalogued as rs889873680; called by muse, mutect2, varscan2
- HIP1 | c.2604G>A p.W868* | Nonsense Mutation (SNP) | VAF 147/517 reads (28%) | catalogued as COSV100417857; called by muse, mutect2, varscan2
- HIVEP2 | c.4180G>A p.V1394M | Missense Mutation (SNP) | VAF 201/430 reads (47%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as COSV50006043; called by muse, mutect2, varscan2
- HJURP | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 128/270 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1263568563; called by muse, mutect2, varscan2
- HLA-DQB2 | c.143G>A p.G48E | Missense Mutation (SNP) | VAF 228/513 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as rs1339860568; called by muse, mutect2, varscan2
- HMGCS1 | c.62C>T p.A21V | Missense Mutation (SNP) | VAF 135/296 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs755388590; called by muse, mutect2, varscan2
- HMGCS2 | c.1463G>A p.G488D | Missense Mutation (SNP) | VAF 142/159 reads (89%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1203892179; called by muse, mutect2, varscan2
- HNF4G | c.1039G>A p.D347N (on ENST00000354370 / NM_001330561.2; = p.D394N on NM_004133.5) | Missense Mutation (SNP) | VAF 104/232 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.597); catalogued as rs1364007068; called by muse, mutect2, varscan2
- HOMER3 | c.128C>T p.A43V | Missense Mutation (SNP) | VAF 148/326 reads (45%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.998); catalogued as rs1217597037, COSV55356949; called by muse, mutect2, varscan2
- HRNR | c.6527G>A p.G2176E | Missense Mutation (SNP) | VAF 204/1582 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.312); catalogued as rs776977716; called by muse, varscan2
- HSD17B2 | c.803-1G>A p.X268_splice | Splice Site (SNP) | VAF 104/216 reads (48%) | catalogued as COSV52276359; called by muse, mutect2, varscan2
- HSF5 | c.205C>T p.P69S | Missense Mutation (SNP) | VAF 232/484 reads (48%) | SIFT tolerated (0.74); PolyPhen benign (0.003); catalogued as rs753671305; called by muse, varscan2
- HSP90AA1 | c.112C>T p.P38S | Missense Mutation (SNP) | VAF 211/511 reads (41%) | PolyPhen benign (0); catalogued as COSV54471976; called by muse, mutect2, varscan2
- HSPBP1 | c.796+1G>A p.X266_splice | Splice Site (SNP) | VAF 136/271 reads (50%) | catalogued as rs746231135; called by muse, mutect2, varscan2
- HTR1F | c.1087C>T p.R363* | Nonsense Mutation (SNP) | VAF 58/151 reads (38%) | catalogued as rs772688320, COSV60389602; called by muse, mutect2, varscan2
- HYDIN | c.9011C>T p.T3004I | Missense Mutation (SNP) | VAF 33/159 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as rs1258849426; called by muse, mutect2, varscan2
- IARS2 | c.572C>T p.A191V | Missense Mutation (SNP) | VAF 83/203 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.589); catalogued as rs1221445040; called by muse, mutect2, varscan2
- IFI35 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 148/289 reads (51%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.575); catalogued as COSV55897118; called by muse, mutect2, varscan2
- IFRD1 | c.641G>A p.C214Y | Missense Mutation (SNP) | VAF 100/407 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.924); catalogued as rs771428735; called by muse, mutect2, varscan2
- IGDCC4 | c.1079G>A p.G360E | Missense Mutation (SNP) | VAF 251/518 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1567084859; called by muse, mutect2, varscan2
- IGF2 | c.311G>A p.R104H (on ENST00000434045 / NM_001127598.3; = p.R48H on NM_000612.6) | Missense Mutation (SNP) | VAF 140/299 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs778465733, COSV56098326; called by muse, mutect2, varscan2
- IGFL4 | c.17C>T p.S6F | Missense Mutation (SNP) | VAF 205/375 reads (55%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as COSV66618966; called by muse, mutect2, varscan2
- IGFN1 | c.1442G>A p.S481N (on ENST00000295591 / NM_001367841.1; = p.S2938N on NM_001164586.2) | Missense Mutation (SNP) | VAF 136/293 reads (46%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.569); catalogued as rs1333316372; called by muse, mutect2, varscan2
- IGHV3-13 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 105/196 reads (54%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.062); catalogued as rs782412840; called by muse, mutect2, varscan2
- IGHV3OR16-8 | c.49G>A p.A17T | Missense Mutation (SNP) | VAF 166/397 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.216); catalogued as rs770618261; called by muse, mutect2, varscan2
- IGKV1-12 | c.92C>T p.S31F | Missense Mutation (SNP) | VAF 54/248 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.148); catalogued as rs1370230548; called by muse, mutect2
- IGSF1 | c.269C>A p.S90* | Nonsense Mutation (SNP) | VAF 34/863 reads (4%) | catalogued as COSV63837621; called by muse, mutect2
- IGSF22 | c.1360G>A p.D454N | Missense Mutation (SNP) | VAF 214/463 reads (46%) | SIFT tolerated (0.34); PolyPhen benign (0.015); catalogued as rs1300311360; called by muse, mutect2, varscan2
- IL17RC | c.448G>A p.D150N (on ENST00000295981 / NM_153461.4; = p.D79N on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 195/426 reads (46%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as rs753024971, COSV55967403; called by muse, mutect2, varscan2
- IL20RB | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 114/275 reads (41%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as COSV59046889; called by muse, mutect2, varscan2
- ING1 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 325/621 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.009); catalogued as rs1305634225; called by muse, mutect2, varscan2
- INMT | c.403G>A p.V135M | Missense Mutation (SNP) | VAF 193/458 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1311740637; called by muse, mutect2, varscan2
- INO80 | c.4448C>T p.S1483F | Missense Mutation (SNP) | VAF 131/251 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs1438181073; called by muse, mutect2, varscan2
- INPP5D | c.1678C>T p.L560F (on ENST00000445964 / NM_001017915.3; = p.L559F on NM_005541.5) | Missense Mutation (SNP) | VAF 165/316 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1357588185; called by muse, mutect2, varscan2
- IPCEF1 | c.74-8C>T | Splice Region (SNP) | VAF 139/248 reads (56%) | catalogued as COSV54550243; called by muse, mutect2, varscan2
- IPO7 | c.263G>A p.R88H | Missense Mutation (SNP) | VAF 152/311 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as rs750326745, COSV65684261; called by muse, mutect2, varscan2
- IPO9 | c.1427G>A p.G476E | Missense Mutation (SNP) | VAF 165/358 reads (46%) | SIFT tolerated (0.33); PolyPhen benign (0.022); catalogued as COSV100843520; called by muse, mutect2, varscan2
- IQCA1L | c.959C>T p.A320V | Missense Mutation (SNP) | VAF 140/456 reads (31%) | SIFT tolerated (0.2); PolyPhen benign (0.01); catalogued as rs542728195; called by muse, mutect2, varscan2
- IQCJ-SCHIP1 | c.1496C>T p.T499I (on ENST00000485419 / NM_001197113.1; = p.T423I on NM_014575.3) | Missense Mutation (SNP) | VAF 136/328 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs760991948; called by muse, mutect2, varscan2
- IQCM | c.809C>T p.P270L | Missense Mutation (SNP) | VAF 104/300 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1386736865; called by muse, mutect2, varscan2
- IQGAP2 | c.1280G>A p.G427E | Missense Mutation (SNP) | VAF 112/265 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as rs144559978; called by muse, mutect2, varscan2
- IQSEC3 | c.523C>T p.L175F | Missense Mutation (SNP) | VAF 193/656 reads (29%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.598); catalogued as COSV100406704; called by muse, mutect2, varscan2
- IRAK1 | c.545G>A p.G182D | Missense Mutation (SNP) | VAF 193/351 reads (55%) | SIFT tolerated (0.46); PolyPhen benign (0.01); catalogued as rs970495832; called by muse, mutect2, varscan2
- IRF2BP2 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 290/536 reads (54%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as rs970480771; called by muse, mutect2, varscan2
- IRF4 | c.25G>A p.G9S | Missense Mutation (SNP) | VAF 205/412 reads (50%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.009); catalogued as rs1285362149; called by muse, mutect2, varscan2
- IRS1 | c.2267C>T p.P756L | Missense Mutation (SNP) | VAF 230/506 reads (45%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs1559159205; called by muse, mutect2, varscan2
- ITGA6 | c.3109C>T p.R1037* (on ENST00000442250; = p.R998* on NM_000210.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 95/193 reads (49%) | catalogued as rs763401432, COSV51230542; called by muse, mutect2, varscan2
- ITGAV | c.1498G>A p.V500I | Missense Mutation (SNP) | VAF 103/259 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.335); catalogued as rs1486595332; called by muse, mutect2, varscan2
- ITGB4 | c.4841G>A p.G1614D | Missense Mutation (SNP) | VAF 257/499 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756507156, COSV52330800; called by muse, mutect2, varscan2
- ITIH2 | c.728G>A p.G243E | Missense Mutation (SNP) | VAF 85/86 reads (99%) | SIFT deleterious (0.04); PolyPhen benign (0.282); catalogued as rs201448963, COSV99059027; called by muse, mutect2, varscan2
- ITPR2 | c.1547C>T p.A516V | Missense Mutation (SNP) | VAF 116/303 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.911); catalogued as COSV67274052; called by muse, mutect2, varscan2
- JADE2 | c.1913G>A p.G638E | Missense Mutation (SNP) | VAF 224/498 reads (45%) | SIFT tolerated (0.63); PolyPhen benign (0.021); catalogued as rs1289969933, COSV50936539; called by muse, mutect2, varscan2
- JAG1 | c.1763C>T p.P588L | Missense Mutation (SNP) | VAF 138/446 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.451); catalogued as CD124897; called by muse, varscan2
- JHY | c.1568C>T p.T523I | Missense Mutation (SNP) | VAF 124/237 reads (52%) | SIFT tolerated (0.23); PolyPhen benign (0.308); catalogued as rs748962617; called by muse, mutect2, varscan2
- JMJD1C | c.2089G>A p.E697K | Missense Mutation (SNP) | VAF 233/234 reads (100%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.746); catalogued as COSV101232545; called by muse, mutect2, varscan2
- JMJD4 | c.124C>T p.P42S | Missense Mutation (SNP) | VAF 233/465 reads (50%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); catalogued as rs1424280144; called by muse, mutect2
- KANK1 | c.1012G>A p.A338T | Missense Mutation (SNP) | VAF 172/357 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as rs1190089437; called by muse, mutect2, varscan2
- KANSL1 | c.1010C>T p.S337F | Missense Mutation (SNP) | VAF 245/799 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as rs777494240, COSV52264702, COSV52267293, COSV99294174; called by muse, mutect2, varscan2
- KATNA1 | c.1111C>T p.R371* | Nonsense Mutation (SNP) | VAF 135/288 reads (47%) | catalogued as rs1358813969, COSV59503467; called by muse, mutect2, varscan2
- KBTBD6 | c.1552G>A p.A518T | Missense Mutation (SNP) | VAF 181/388 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV65270838; called by muse, mutect2, varscan2
- KCNN2 | c.809C>T p.A270V (on ENST00000264773; = p.A482V on NM_021614.4) | Missense Mutation (SNP) | VAF 151/339 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.031); catalogued as COSV53288131; called by muse, mutect2, varscan2
- KCNN3 | c.2089C>T p.R697C (on ENST00000618040 / NM_001204087.1; = p.R682C on NM_002249.6) | Missense Mutation (SNP) | VAF 262/530 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as rs1209698715, COSV55214864; called by muse, varscan2
- KCTD13 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 217/475 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.652); catalogued as COSV58161203; called by muse, mutect2, varscan2
- KDM5C | c.509G>A p.G170E | Missense Mutation (SNP) | VAF 124/318 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as CD1211638, COSV62891170; called by muse, mutect2, varscan2
- KDSR | c.646C>T p.P216S | Missense Mutation (SNP) | VAF 117/278 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1373109929; called by muse, mutect2, varscan2
- KEL | c.887G>A p.G296D | Missense Mutation (SNP) | VAF 268/854 reads (31%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs1371966394; called by muse, mutect2, varscan2
- KIAA0753 | c.1024C>T p.Q342* | Nonsense Mutation (SNP) | VAF 165/371 reads (44%) | catalogued as rs1300992961; called by muse, mutect2, varscan2
- KIAA0753 | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 140/255 reads (55%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.977); catalogued as rs778952620; called by muse, mutect2, varscan2
- KIAA2026 | c.3214C>T p.Q1072* | Nonsense Mutation (SNP) | VAF 165/330 reads (50%) | catalogued as rs1355805019; called by muse, mutect2, varscan2
- KIF19 | c.1259G>A p.G420E | Missense Mutation (SNP) | VAF 151/334 reads (45%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as rs1395344368, COSV63429591; called by muse, mutect2, varscan2
- KIF21A | c.58C>T p.L20F | Missense Mutation (SNP) | VAF 111/303 reads (37%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as rs1196836806; called by muse, mutect2, varscan2
- KIFC2 | c.1351G>A p.V451I | Missense Mutation (SNP) | VAF 171/363 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.885); catalogued as COSV104398412; called by muse, mutect2, varscan2
- KIRREL2 | c.539G>A p.G180E | Missense Mutation (SNP) | VAF 150/312 reads (48%) | SIFT deleterious (0.04); PolyPhen benign (0.158); catalogued as COSV52879728; called by muse, mutect2, varscan2
- KIRREL3 | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 236/544 reads (43%) | SIFT tolerated (0.4); PolyPhen benign (0.036); catalogued as rs200640353, COSV69384397; ClinVar: uncertain significance; called by muse, mutect2
- KL | c.2951C>T p.A984V | Missense Mutation (SNP) | VAF 148/294 reads (50%) | SIFT tolerated (0.97); PolyPhen benign (0.001); catalogued as COSV66308455; called by muse, mutect2, varscan2
- KLC1 | c.495G>A p.E165= | Splice Region (SNP) | VAF 107/258 reads (41%) | catalogued as rs1319050467; called by muse, mutect2, varscan2
- KLF14 | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 264/844 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as rs1554471172; called by muse, mutect2
- KLF4 | c.1049C>T p.S350F | Missense Mutation (SNP) | VAF 185/427 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV65929181; called by muse, mutect2, varscan2
- KLF9 | c.224C>T p.P75L | Missense Mutation (SNP) | VAF 259/489 reads (53%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); catalogued as COSV101009587; called by muse, mutect2, varscan2
- KLHL25 | c.881G>A p.G294D | Missense Mutation (SNP) | VAF 222/447 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.117); catalogued as rs1187686856; called by muse, varscan2
- KLHL29 | c.934C>T p.P312S | Missense Mutation (SNP) | VAF 150/287 reads (52%) | SIFT tolerated (0.27); PolyPhen benign (0.26); catalogued as rs764338662, COSV56022934; called by muse, mutect2, varscan2
- KLK8 | c.88G>A p.E30K | Missense Mutation (SNP) | VAF 218/442 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV51593357; called by muse, mutect2, varscan2
- KLRC1 | c.299G>A p.R100K | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as rs745712014; called by muse, mutect2, varscan2
- KLRC4 | c.56G>A p.R19K | Missense Mutation (SNP) | VAF 163/315 reads (52%) | SIFT tolerated (0.26); PolyPhen benign (0.275); catalogued as rs1246870907; called by muse, mutect2, varscan2
- KLRG2 | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 120/495 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.349); catalogued as rs747913001; called by muse, mutect2, varscan2
- KMT2A | c.3734C>T p.T1245I | Missense Mutation (SNP) | VAF 188/403 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as rs528361199; called by muse, mutect2, varscan2
- KMT2C | c.8986G>A p.G2996S | Missense Mutation (SNP) | VAF 180/654 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.012); catalogued as COSV51485906; called by muse, mutect2, varscan2
- KMT5A | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 142/279 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.673); catalogued as COSV100389523; called by muse, mutect2, varscan2
- KPTN | c.629C>T p.P210L | Missense Mutation (SNP) | VAF 162/370 reads (44%) | SIFT deleterious (0.05); PolyPhen benign (0.424); catalogued as rs1354205960; called by muse, mutect2, varscan2
- KRBA1 | c.3037C>T p.L1013F | Missense Mutation (SNP) | VAF 225/780 reads (29%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1243249023, COSV55443519; called by muse, mutect2, varscan2
- KRT14 | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 164/294 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV99390894, COSV99391035; called by muse, mutect2, varscan2
- KRT3 | c.556G>A p.E186K | Missense Mutation (SNP) | VAF 202/449 reads (45%) | SIFT deleterious (0.03); PolyPhen benign (0.298); catalogued as COSV58815646; called by muse, mutect2, varscan2
- KRT8 | c.89G>A p.G30D | Missense Mutation (SNP) | VAF 294/512 reads (57%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.768); catalogued as rs777050332; called by muse, varscan2
- KRT82 | c.1068G>A p.Q356= | Splice Region (SNP) | VAF 155/278 reads (56%) | catalogued as rs1191605458, COSV57786242; called by muse, mutect2, varscan2
- KRT85 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 180/468 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.479); catalogued as rs150588972; called by muse, mutect2, varscan2
- KRT86 | c.1039G>A p.E347K | Missense Mutation (SNP) | VAF 179/393 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs756000963; called by muse, mutect2, varscan2
- KRTAP1-4 | c.250C>T p.P84S | Missense Mutation (SNP) | VAF 246/520 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs570061915, COSV60337275; called by muse, mutect2, varscan2
- KRTAP24-1 | c.644C>T p.P215L | Missense Mutation (SNP) | VAF 198/386 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs771006844; called by muse, mutect2, varscan2
- KRTAP5-3 | c.137G>A p.C46Y | Missense Mutation (SNP) | VAF 261/548 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs1300947110; called by muse, mutect2, varscan2
- KSR1 | c.1274C>T p.T425I (on ENST00000644974 / NM_001367810.1; = p.T288I on NM_014238.2) | Missense Mutation (SNP) | VAF 109/249 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.966); catalogued as rs1214294095, COSV104392353; called by muse, mutect2, varscan2
- KSR2 | c.2840C>T p.S947F | Missense Mutation (SNP) | VAF 141/257 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100196676; called by muse, mutect2, varscan2
- KYNU | c.925G>A p.E309K | Missense Mutation (SNP) | VAF 100/250 reads (40%) | SIFT tolerated (0.96); PolyPhen benign (0.005); catalogued as COSV51585309; called by muse, mutect2, varscan2
- LACC1 | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 86/171 reads (50%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0.003); catalogued as rs779989984; called by muse, mutect2, varscan2
- LAMA2 | c.232G>A p.V78M | Missense Mutation (SNP) | VAF 154/317 reads (49%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.837); catalogued as rs1426674838, COSV70352852; called by muse, mutect2, varscan2
- LAMB2 | c.3742C>T p.R1248C | Missense Mutation (SNP) | VAF 236/469 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs372230106, COSV59734867; called by muse, mutect2, varscan2
- LAMB3 | c.3361G>A p.E1121K | Missense Mutation (SNP) | VAF 183/374 reads (49%) | SIFT tolerated (0.62); PolyPhen benign (0.026); catalogued as rs887338434; called by muse, mutect2, varscan2
- LAMB3 | c.2359C>T p.L787F | Missense Mutation (SNP) | VAF 113/208 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as rs940478971; called by muse, mutect2, varscan2
- LAMC3 | c.3875C>T p.T1292I | Missense Mutation (SNP) | VAF 205/429 reads (48%) | SIFT tolerated (0.12); PolyPhen benign (0.045); catalogued as COSV62654701; called by muse, mutect2, varscan2
- LARP7 | c.482C>T p.S161F | Missense Mutation (SNP) | VAF 118/247 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs867964802; called by mutect2, varscan2
- LBR | c.1592G>A p.G531E | Missense Mutation (SNP) | VAF 138/285 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55287907; called by muse, mutect2, varscan2
- LCA5L | c.356C>T p.T119I | Missense Mutation (SNP) | VAF 139/298 reads (47%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs376670598; called by muse, mutect2, varscan2
- LCP1 | c.1021G>A p.A341T | Missense Mutation (SNP) | VAF 172/339 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.077); catalogued as rs1203778170; called by muse, mutect2, varscan2
- LCT | c.2501C>T p.S834F | Missense Mutation (SNP) | VAF 231/442 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51547054; called by muse, mutect2, varscan2
- LDB3 | c.2171C>T p.T724I | Missense Mutation (SNP) | VAF 135/137 reads (99%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as rs181027948; called by muse, mutect2, varscan2
- LGALS9B | c.128C>T p.T43I | Missense Mutation (SNP) | VAF 146/153 reads (95%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); catalogued as COSV60864292; called by muse, mutect2, varscan2
- LHFPL5 | c.20C>T p.A7V | Missense Mutation (SNP) | VAF 99/252 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV64177953; called by muse, mutect2, varscan2
- LHFPL5 | c.110C>T p.S37F | Missense Mutation (SNP) | VAF 238/474 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as COSV64177716; called by muse, mutect2, varscan2
- LIFR | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 96/202 reads (48%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs1040209210; called by muse, mutect2, varscan2
- LILRA2 | c.1348C>T p.L450F (on ENST00000391738 / NM_001130917.3; = p.L433F on NM_006866.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 235/512 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV52198985; called by muse, mutect2, varscan2
- LILRA4 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 123/248 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.623); catalogued as COSV52494442; called by muse, mutect2, varscan2
- LMAN1 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 204/452 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1233606542; called by muse, mutect2, varscan2
- LMNTD1 | c.605C>T p.S202F | Missense Mutation (SNP) | VAF 87/256 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV99280251; called by muse, mutect2, varscan2
- LMO7 | c.3060G>A p.Q1020= (on ENST00000357063; = p.Q701= on NM_005358.5) | Splice Region (SNP) | VAF 81/168 reads (48%) | catalogued as COSV100413712; called by muse, mutect2, varscan2
- LMTK2 | c.4144G>A p.E1382K | Missense Mutation (SNP) | VAF 270/878 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.058); catalogued as COSV51994494; called by muse, mutect2
- LONP2 | c.2452G>A p.D818N | Missense Mutation (SNP) | VAF 186/396 reads (47%) | SIFT tolerated (0.23); PolyPhen benign (0.037); catalogued as rs755334449; called by muse, mutect2, varscan2
- LOXHD1 | c.1918G>A p.V640M | Missense Mutation (SNP) | VAF 186/392 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as rs905785369; called by muse, mutect2, varscan2
- LRFN1 | c.2306G>A p.S769N | Missense Mutation (SNP) | VAF 328/677 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.746); catalogued as rs895734883; called by muse, mutect2, varscan2
- LRFN1 | c.80G>A p.G27E | Missense Mutation (SNP) | VAF 216/448 reads (48%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.672); catalogued as rs1437092118; called by muse, mutect2, varscan2
- LRP12 | c.2009G>A p.G670E | Missense Mutation (SNP) | VAF 158/360 reads (44%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.621); catalogued as rs778367927, COSV99407522; called by muse, mutect2, varscan2
- LRP1B | c.6604C>T p.L2202F | Missense Mutation (SNP) | VAF 124/302 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.567); catalogued as COSV67186573; called by muse, mutect2
- LRP3 | c.1150G>A p.G384S | Missense Mutation (SNP) | VAF 226/527 reads (43%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs1271284176, COSV53504795; called by muse, mutect2
- LRPPRC | c.3708G>A p.K1236= | Splice Region (SNP) | VAF 101/211 reads (48%) | catalogued as rs1408952346; called by muse, mutect2, varscan2
- LRRC49 | c.7C>T p.P3S | Missense Mutation (SNP) | VAF 163/345 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV51437299; called by muse, mutect2, varscan2
- LRRC4C | c.103C>T p.L35F | Missense Mutation (SNP) | VAF 181/379 reads (48%) | SIFT tolerated (0.14); PolyPhen benign (0.42); catalogued as rs1352348534; called by muse, mutect2, varscan2
- LRRC71 | c.1199G>A p.G400E | Missense Mutation (SNP) | VAF 163/336 reads (49%) | SIFT deleterious (0.01); PolyPhen benign (0.436); catalogued as rs536557466; called by muse, mutect2, varscan2
- LRRN2 | c.137C>T p.S46F | Missense Mutation (SNP) | VAF 235/531 reads (44%) | SIFT deleterious (0.01); PolyPhen benign (0.135); catalogued as COSV65784108; called by muse, mutect2, varscan2
- LSG1 | c.161C>T p.T54I | Missense Mutation (SNP) | VAF 125/277 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as COSV54569942; called by muse, mutect2, varscan2
- LYST | c.4427C>T p.S1476F | Missense Mutation (SNP) | VAF 170/334 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV67715228; called by muse, mutect2, varscan2
- LYST | c.619C>T p.R207C | Missense Mutation (SNP) | VAF 131/295 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs748789807, COSV67704112; called by muse, mutect2, varscan2
- LZTS3 | c.1784G>A p.G595D (on ENST00000329152; = p.G549D on NM_001282533.2) | Missense Mutation (SNP) | VAF 271/854 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.757); catalogued as rs749165745; called by muse, mutect2, varscan2
- MAB21L2 | c.568C>T p.P190S | Missense Mutation (SNP) | VAF 145/331 reads (44%) | SIFT tolerated (0.45); PolyPhen benign (0.047); catalogued as rs1398131833; called by muse, mutect2, varscan2
- MACF1 | c.14527G>A p.E4843K (on ENST00000372915; = p.E2776K on NM_012090.5) | Missense Mutation (SNP) | VAF 146/275 reads (53%) | catalogued as COSV57107651; called by muse, mutect2, varscan2
- MADD | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 135/311 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1278535514; called by muse, mutect2, varscan2
- MAGEC1 | c.208C>T p.P70S | Missense Mutation (SNP) | VAF 273/611 reads (45%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.003); catalogued as COSV53581313; called by muse, mutect2, varscan2
- MAGEL2 | c.2585C>T p.P862L | Missense Mutation (SNP) | VAF 181/396 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.876); catalogued as COSV99041386; called by muse, mutect2, varscan2
- MAMDC2 | c.170C>T p.T57I | Missense Mutation (SNP) | VAF 149/310 reads (48%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV65856679; called by muse, mutect2, varscan2
- MAMDC4 | c.938C>T p.S313F | Missense Mutation (SNP) | VAF 169/357 reads (47%) | SIFT tolerated (0.72); PolyPhen benign (0.046); catalogued as rs373389983; called by muse, mutect2, varscan2
- MAN2C1 | c.164C>T p.P55L | Missense Mutation (SNP) | VAF 211/419 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.147); catalogued as COSV99145182; called by muse, mutect2, varscan2
- MAP2 | c.2866G>A p.A956T | Missense Mutation (SNP) | VAF 111/247 reads (45%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.129); catalogued as COSV52284961; called by muse, mutect2, varscan2
- MAP2K7 | c.257G>A p.S86N | Missense Mutation (SNP) | VAF 143/335 reads (43%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1331007401; called by muse, mutect2, varscan2
- MAP3K9 | c.2794C>T p.P932S (on ENST00000554752 / NM_001284230.1; = p.P946S on NM_033141.4) | Missense Mutation (SNP) | VAF 154/347 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.054); catalogued as rs1462257851; called by muse, mutect2, varscan2
- MAPKAP1 | c.175G>A p.G59S | Missense Mutation (SNP) | VAF 171/343 reads (50%) | SIFT tolerated (0.77); PolyPhen benign (0.403); catalogued as COSV56367193; called by muse, mutect2, varscan2
- MBLAC1 | c.187C>T p.R63C | Missense Mutation (SNP) | VAF 255/872 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.183); catalogued as rs990815356; called by muse, mutect2, varscan2
- MBOAT7 | c.28G>A p.V10M | Missense Mutation (SNP) | VAF 206/485 reads (42%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs1164469093; called by muse, mutect2, varscan2
- MCHR1 | c.1111G>A p.A371T | Missense Mutation (SNP) | VAF 282/301 reads (94%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as rs756655137; called by muse, mutect2, varscan2
- MCM6 | c.817G>A p.V273I | Missense Mutation (SNP) | VAF 164/370 reads (44%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as rs777868882; called by muse, mutect2, varscan2
- MCM8 | c.1690G>A p.G564R | Missense Mutation (SNP) | VAF 147/529 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs777607058; called by muse, mutect2, varscan2
- MCOLN3 | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 98/209 reads (47%) | SIFT tolerated (0.7); PolyPhen possibly damaging (0.451); catalogued as rs765430597; called by muse, mutect2, varscan2
- MCPH1 | c.1849C>T p.H617Y | Missense Mutation (SNP) | VAF 156/336 reads (46%) | SIFT tolerated (0.46); PolyPhen benign (0.02); catalogued as rs764861033; called by muse, mutect2, varscan2
- MDN1 | c.15007G>A p.G5003S | Missense Mutation (SNP) | VAF 128/271 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.573); catalogued as rs1454148074; called by muse, mutect2
- MDN1 | c.13025G>A p.G4342E | Missense Mutation (SNP) | VAF 186/370 reads (50%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.011); catalogued as rs1001701513; called by muse, mutect2, varscan2
- MEAF6 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 131/259 reads (51%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); catalogued as COSV56164722; called by muse, mutect2, varscan2
- MECP2 | c.986G>A p.G329D | Missense Mutation (SNP) | VAF 266/491 reads (54%) | SIFT deleterious (0.04); PolyPhen benign (0.025); catalogued as rs781897686, COSV57656340; called by muse, mutect2, varscan2
- MED1 | c.3683G>A p.G1228D | Missense Mutation (SNP) | VAF 170/389 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); catalogued as COSV56125761; called by muse, mutect2, varscan2
- MED13L | c.344C>T p.S115F | Missense Mutation (SNP) | VAF 115/233 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56121295; called by muse, mutect2, varscan2
- MED16 | c.2264C>T p.A755V | Missense Mutation (SNP) | VAF 266/563 reads (47%) | SIFT tolerated (0.25); PolyPhen benign (0.04); catalogued as rs200816964; called by muse, mutect2, varscan2
- MEF2A | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 128/308 reads (42%) | SIFT tolerated (0.12); PolyPhen probably damaging (1); catalogued as COSV57530499; called by muse, mutect2, varscan2
- MEGF11 | c.98+1G>A p.X33_splice | Splice Site (SNP) | VAF 143/346 reads (41%) | catalogued as rs1342135949; called by muse, mutect2, varscan2
- MEGF8 | c.287G>A p.G96E | Missense Mutation (SNP) | VAF 155/393 reads (39%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.572); catalogued as rs780016069; called by muse, mutect2, varscan2
- MEPCE | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 251/890 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs1434668065; called by muse, mutect2, varscan2
- METTL14 | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 180/351 reads (51%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); catalogued as rs760341846; called by muse, mutect2, varscan2
- METTL15 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 198/395 reads (50%) | SIFT tolerated (0.08); PolyPhen benign (0.02); catalogued as COSV57722986; called by muse, mutect2, varscan2
- MIA2 | c.1493G>A p.G498E | Missense Mutation (SNP) | VAF 67/166 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1357689526; called by muse, mutect2, varscan2
- MIA2 | c.2083C>T p.P695S | Missense Mutation (SNP) | VAF 162/334 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.094); catalogued as rs1014007578; called by muse, mutect2
- MIA3 | c.3217G>A p.E1073K | Missense Mutation (SNP) | VAF 166/348 reads (48%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV100719420; called by muse, mutect2, varscan2
- MIB1 | c.1825C>T p.P609S | Missense Mutation (SNP) | VAF 120/246 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV55095874; called by muse, mutect2, varscan2
- MICALL2 | c.2411C>T p.A804V | Missense Mutation (SNP) | VAF 70/539 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.026); catalogued as rs1420579279; called by muse, mutect2, varscan2
- MINDY4 | c.2263C>T p.P755S | Missense Mutation (SNP) | VAF 174/421 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs774475960; called by muse, mutect2, varscan2
- MINK1 | c.1148C>T p.P383L | Missense Mutation (SNP) | VAF 246/536 reads (46%) | SIFT tolerated (0.18); PolyPhen benign (0.039); catalogued as rs1456033048, COSV61790189; called by muse, mutect2, varscan2
- MIOS | c.1028C>T p.P343L | Missense Mutation (SNP) | VAF 65/245 reads (27%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs1161451253; called by muse, mutect2, varscan2
- MIS18BP1 | c.2116C>T p.H706Y | Missense Mutation (SNP) | VAF 105/265 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1265106089; called by muse, mutect2, varscan2
- MLLT10 | c.1091C>T p.S364F | Missense Mutation (SNP) | VAF 139/139 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV57002843; called by muse, mutect2, varscan2
- MMAB | c.696del p.N233Ifs*7 | Frame Shift Del (DEL) | VAF 151/370 reads (41%) | catalogued as COSV99904655; called by mutect2, pindel, varscan2
- MMP11 | c.422C>T p.T141M | Missense Mutation (SNP) | VAF 189/529 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs755891150, COSV53157295; called by muse, mutect2, varscan2
- MMP11 | c.704C>T p.A235V | Missense Mutation (SNP) | VAF 280/479 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); catalogued as COSV53156486; called by muse, mutect2, varscan2
- MMP14 | c.313G>A p.A105T | Missense Mutation (SNP) | VAF 200/414 reads (48%) | SIFT tolerated (0.63); PolyPhen benign (0.006); catalogued as rs776709320; called by muse, mutect2, varscan2
- MMP16 | c.593C>T p.P198L | Missense Mutation (SNP) | VAF 164/388 reads (42%) | SIFT tolerated (0.15); PolyPhen benign (0.366); catalogued as COSV54182863, COSV54192050; called by muse, mutect2, varscan2
- MMP19 | c.1407G>A p.W469* | Nonsense Mutation (SNP) | VAF 236/462 reads (51%) | catalogued as COSV100490915; called by muse, mutect2, varscan2
- MMP9 | c.1764G>A p.W588* | Nonsense Mutation (SNP) | VAF 157/547 reads (29%) | catalogued as rs200746714; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MNS1 | c.1207G>A p.E403K | Missense Mutation (SNP) | VAF 215/418 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53068603; called by muse, mutect2, varscan2
- MPDZ | c.4655C>T p.A1552V | Missense Mutation (SNP) | VAF 124/238 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.033); catalogued as COSV59925128; called by muse, mutect2, varscan2
- MPND | c.131G>A p.G44D | Missense Mutation (SNP) | VAF 246/512 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.068); catalogued as rs1333590444; called by muse, mutect2, varscan2
- MPP1 | c.1342G>A p.E448K | Missense Mutation (SNP) | VAF 353/646 reads (55%) | SIFT tolerated (0.27); PolyPhen benign (0.058); catalogued as COSV65729327; called by muse, varscan2
- MROH1 | c.288G>A p.M96I | Missense Mutation (SNP) | VAF 143/304 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs967831207; called by muse, mutect2, varscan2
- MROH2B | c.1582G>A p.A528T | Missense Mutation (SNP) | VAF 154/304 reads (51%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV68182407; called by muse, mutect2, varscan2
- MRPL2 | c.73C>T p.P25S | Missense Mutation (SNP) | VAF 217/535 reads (41%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.003); catalogued as rs1229750729; called by muse, mutect2, varscan2
- MRPL47 | c.295C>T p.H99Y | Missense Mutation (SNP) | VAF 96/222 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs772376694; called by muse, mutect2, varscan2
- MRS2 | c.166G>A p.G56R | Missense Mutation (SNP) | VAF 190/391 reads (49%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0); catalogued as rs1412443081, COSV99219185; called by muse, mutect2, varscan2
- MRS2 | c.832G>A p.V278I | Missense Mutation (SNP) | VAF 126/258 reads (49%) | SIFT tolerated (0.26); PolyPhen benign (0.015); catalogued as rs1046631107; called by muse, mutect2, varscan2
- MS4A10 | c.733G>A p.V245I | Missense Mutation (SNP) | VAF 131/277 reads (47%) | SIFT tolerated, low confidence (0.85); PolyPhen benign (0.014); catalogued as rs1249759829, CM1212888; called by muse, mutect2, varscan2
- MS4A14 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 95/205 reads (46%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as rs201462421; called by muse, mutect2, varscan2
- MS4A5 | c.350G>A p.S117N | Missense Mutation (SNP) | VAF 96/221 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.02); catalogued as COSV55739976; called by muse, mutect2, varscan2
- MSH6 | c.320C>T p.P107L | Missense Mutation (SNP) | VAF 178/361 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs878853732; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MSH6 | c.1370C>T p.A457V | Missense Mutation (SNP) | VAF 166/326 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52279303, COSV52283570; called by muse, mutect2, varscan2
- MTCL1 | c.4372G>A p.G1458R (on ENST00000306329 / NM_001378206.1; = p.G1139R on NM_015210.4) | Missense Mutation (SNP) | VAF 216/484 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.444); catalogued as rs749887150; called by muse, mutect2, varscan2
- MTERF1 | c.662C>T p.A221V | Missense Mutation (SNP) | VAF 143/590 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs760617203; called by muse, mutect2, varscan2
- MTF1 | c.1642C>T p.P548S | Missense Mutation (SNP) | VAF 163/352 reads (46%) | SIFT deleterious (0.05); PolyPhen benign (0.012); catalogued as rs1425814607; called by muse, mutect2, varscan2
- MTHFS | c.23G>A p.S8N | Missense Mutation (SNP) | VAF 156/338 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs937096410; called by muse, mutect2, varscan2
- MTMR4 | c.2726G>A p.S909N | Missense Mutation (SNP) | VAF 248/470 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.629); catalogued as rs1171740055; called by muse, mutect2, varscan2
- MTRF1 | c.863C>T p.P288L | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.096); catalogued as COSV101067411; called by muse, mutect2, varscan2
- MTUS1 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 169/338 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.316); catalogued as rs771470221; called by muse, mutect2, varscan2
- MUC12 | c.1642G>A p.A548T (on ENST00000379442; = p.A405T on NM_001164462.1) | Missense Mutation (SNP) | VAF 190/1337 reads (14%) | SIFT tolerated (0.91); PolyPhen possibly damaging (0.451); catalogued as rs530837222, COSV65186239; called by muse, mutect2, varscan2
- MUC12 | c.5309C>T p.S1770F (on ENST00000379442; = p.S1627F on NM_001164462.1) | Missense Mutation (SNP) | VAF 254/1056 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.496); catalogued as rs1409352665; called by muse, varscan2
- MUC16 | c.42550G>A p.D14184N | Missense Mutation (SNP) | VAF 118/246 reads (48%) | SIFT tolerated, low confidence (0.59); PolyPhen probably damaging (0.985); catalogued as rs953478374; called by muse, mutect2, varscan2
- MUC16 | c.22394C>T p.T7465I | Missense Mutation (SNP) | VAF 198/417 reads (47%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.047); catalogued as rs775758151; called by muse, mutect2, varscan2
- MUC16 | c.19199G>A p.R6400K | Missense Mutation (SNP) | VAF 157/316 reads (50%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.003); catalogued as COSV67446917; called by muse, mutect2, varscan2
- MUC17 | c.3118G>A p.G1040R | Missense Mutation (SNP) | VAF 183/1400 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs1223312215; called by muse, varscan2
- MUC4 | c.8867G>A p.G2956D | Missense Mutation (SNP) | VAF 84/594 reads (14%) | SIFT tolerated, low confidence (0.2); PolyPhen probably damaging (0.934); catalogued as rs765166855; called by muse, mutect2, varscan2
- MUC5B | c.1910C>T p.S637F | Missense Mutation (SNP) | VAF 207/463 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1432888001; called by muse, mutect2, varscan2
- MUC5B | c.12446G>A p.G4149D | Missense Mutation (SNP) | VAF 307/724 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.727); catalogued as rs757132951, COSV71590670; called by muse, mutect2, varscan2
- MXRA5 | c.2113G>A p.G705R | Missense Mutation (SNP) | VAF 248/485 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.211); catalogued as COSV54254545; called by muse, mutect2, varscan2
- MYBPC2 | c.467C>T p.P156L | Missense Mutation (SNP) | VAF 133/256 reads (52%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs1310193682; called by muse, mutect2, varscan2
- MYC | c.1222G>A p.A408T (on ENST00000377970; = p.A423T on NM_002467.6) | Missense Mutation (SNP) | VAF 139/405 reads (34%) | SIFT tolerated (0.25); PolyPhen benign (0.005); catalogued as rs1332562282; called by muse, mutect2, varscan2
- MYCBPAP | c.2036G>T p.S679I | Missense Mutation (SNP) | VAF 56/452 reads (12%) | SIFT tolerated (0.24); PolyPhen benign (0.031); catalogued as rs1351633239; called by muse, mutect2, varscan2
- MYD88 | c.367G>A p.E123K | Missense Mutation (SNP) | VAF 182/380 reads (48%) | SIFT tolerated (0.56); PolyPhen benign (0.003); catalogued as rs750897932; called by muse, varscan2
- MYH14 | c.2623G>A p.A875T | Missense Mutation (SNP) | VAF 241/513 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.196); catalogued as rs1288887461; called by muse, mutect2, varscan2
- MYH15 | c.4786G>A p.E1596K | Missense Mutation (SNP) | VAF 85/190 reads (45%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.627); catalogued as COSV56306543; called by muse, mutect2, varscan2
- MYLK | c.4079G>A p.G1360D | Missense Mutation (SNP) | VAF 186/426 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587782967, COSV60612967; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYO15A | c.8148G>A p.Q2716= | Splice Region (SNP) | VAF 167/381 reads (44%) | catalogued as CM013772; called by muse, mutect2, varscan2
- MYO16 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 153/341 reads (45%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.478); catalogued as COSV51814391; called by muse, mutect2, varscan2
- MYO1E | c.3208C>T p.L1070F | Missense Mutation (SNP) | VAF 141/308 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs1443405388; called by muse, mutect2, varscan2
- MYO1F | c.1182G>A p.Q394= | Splice Region (SNP) | VAF 146/322 reads (45%) | catalogued as COSV100596922; called by muse, mutect2, varscan2
- MYO1H | c.1318G>A p.E440K | Missense Mutation (SNP) | VAF 93/209 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1456991224; called by muse, mutect2, varscan2
- MYO5B | c.802G>A p.A268T | Missense Mutation (SNP) | VAF 144/266 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.471); catalogued as rs757208688; called by muse, mutect2, varscan2
- MYOZ3 | c.723G>A p.W241* | Nonsense Mutation (SNP) | VAF 143/336 reads (43%) | catalogued as rs922308102; called by muse, mutect2, varscan2
- MYT1 | c.2927C>T p.A976V | Missense Mutation (SNP) | VAF 174/557 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.17); catalogued as rs1233045835; called by muse, mutect2, varscan2
- NAA20 | c.395G>A p.R132K | Missense Mutation (SNP) | VAF 192/546 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.12); catalogued as COSV58549211; called by muse, mutect2, varscan2
- NAB1 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 206/475 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.463); catalogued as rs767391567; called by muse, mutect2, varscan2
- NAPSA | c.1232G>A p.G411E | Missense Mutation (SNP) | VAF 208/408 reads (51%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.133); catalogued as rs764770251; called by muse, mutect2, varscan2
- NASP | c.1115C>T p.P372L | Missense Mutation (SNP) | VAF 224/395 reads (57%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs1267035892; called by muse, mutect2, varscan2
- NBAS | c.2203G>A p.E735K | Missense Mutation (SNP) | VAF 113/215 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs1360905462; called by muse, mutect2, varscan2
- NBAS | c.284C>T p.A95V | Missense Mutation (SNP) | VAF 122/291 reads (42%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.669); catalogued as CM1513235; called by muse, mutect2, varscan2
- NBEA | c.5126C>T p.S1709F | Missense Mutation (SNP) | VAF 180/368 reads (49%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.276); catalogued as rs1210919502; called by muse, mutect2, varscan2
- NBEAL1 | c.6739G>A p.A2247T | Missense Mutation (SNP) | VAF 121/249 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779654980; called by muse, mutect2, varscan2
- NBPF1 | c.1234G>A p.G412R | Missense Mutation (SNP) | VAF 37/341 reads (11%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.857); catalogued as rs777338419; called by muse, mutect2, varscan2
- NCAPD3 | c.4378C>T p.P1460S | Missense Mutation (SNP) | VAF 163/363 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.927); catalogued as rs986655732; called by muse, mutect2, varscan2
- NCKAP5L | c.1361G>A p.R454K | Missense Mutation (SNP) | VAF 232/480 reads (48%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs764585478; called by muse, mutect2, varscan2
- NCOA2 | c.1595G>A p.S532N | Missense Mutation (SNP) | VAF 209/448 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.194); catalogued as rs1434124016; called by muse, mutect2, varscan2
- NDUFS2 | c.397C>T p.L133F | Missense Mutation (SNP) | VAF 108/259 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.482); catalogued as COSV100917553; called by muse, mutect2, varscan2
- NDUFS4 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 154/306 reads (50%) | SIFT tolerated (0.73); PolyPhen benign (0.001); catalogued as rs1364096749; called by muse, mutect2, varscan2
- NEB | c.9889G>A p.V3297I | Missense Mutation (SNP) | VAF 161/322 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as rs1358452379; called by muse, mutect2, varscan2
- NEB | c.9302G>A p.C3101Y | Missense Mutation (SNP) | VAF 215/414 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99420136; called by muse, mutect2, varscan2
- NECAP1 | c.302G>A p.G101E | Missense Mutation (SNP) | VAF 84/207 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100331568; called by muse, varscan2
- NEIL1 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 283/622 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV61833107; called by muse, mutect2, varscan2
- NEK7 | c.28G>A p.G10R | Missense Mutation (SNP) | VAF 119/268 reads (44%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0.076); catalogued as COSV66311727; called by muse, mutect2, varscan2
- NFATC1 | c.2393C>T p.P798L | Missense Mutation (SNP) | VAF 230/491 reads (47%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as rs756675542; called by muse, varscan2
- NFE2L1 | c.1112G>A p.C371Y | Missense Mutation (SNP) | VAF 239/488 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs145613290; called by muse, mutect2, varscan2
- NGLY1 | c.1109G>A p.G370D | Missense Mutation (SNP) | VAF 45/285 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs757885829; called by muse, mutect2, varscan2
- NHS | c.415C>T p.L139F | Missense Mutation (SNP) | VAF 247/537 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.849); catalogued as rs866391919; called by muse, mutect2, varscan2
- NIBAN2 | c.705+1G>A p.X235_splice | Splice Site (SNP) | VAF 122/267 reads (46%) | catalogued as COSV100964887; called by muse, mutect2, varscan2
- NIBAN3 | c.1972C>T p.R658W | Missense Mutation (SNP) | VAF 189/363 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); catalogued as rs1405645522; called by muse, mutect2, varscan2
- NLRP13 | c.1177G>A p.V393I | Missense Mutation (SNP) | VAF 163/328 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.506); catalogued as COSV61620939; called by muse, mutect2, varscan2
- NLRX1 | c.1307G>A p.G436E | Missense Mutation (SNP) | VAF 234/491 reads (48%) | SIFT deleterious (0.03); PolyPhen benign (0.273); catalogued as rs762365380; called by muse, mutect2, varscan2
- NOM1 | c.1247G>A p.S416N | Missense Mutation (SNP) | VAF 172/577 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.033); catalogued as COSV99315518; called by muse, varscan2
- NOS3 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 246/920 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs1450752209; called by muse, mutect2
- NOS3 | c.3427G>A p.G1143S | Missense Mutation (SNP) | VAF 60/681 reads (9%) | SIFT tolerated (0.37); PolyPhen probably damaging (0.964); catalogued as rs1404613427; called by muse, mutect2
- NOSTRIN | c.1180-1G>A p.X394_splice (on ENST00000317647 / NM_001039724.4; = p.X316_splice on NM_052946.3) | Splice Site (SNP) | VAF 120/235 reads (51%) | catalogued as COSV100473884; called by muse, mutect2, varscan2
- NOTCH4 | c.2228C>T p.S743F | Missense Mutation (SNP) | VAF 244/556 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV66679074, COSV66683777; called by muse, mutect2, varscan2
- NOXA1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 235/499 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs1371095473; called by muse, mutect2, varscan2
- NPAS3 | c.185C>T p.S62F (on ENST00000356141 / NM_001164749.2; = p.S32F on NM_022123.3) | Missense Mutation (SNP) | VAF 129/300 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs753933637; called by muse, mutect2, varscan2
- NPC1L1 | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 159/482 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs775686319; called by muse, mutect2, varscan2
- NR2F6 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 172/340 reads (51%) | SIFT tolerated (0.09); PolyPhen benign (0.393); catalogued as rs774276278; called by muse, mutect2, varscan2
- NRF1 | c.1021G>A p.V341I | Missense Mutation (SNP) | VAF 133/455 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.846); catalogued as rs1289727703; called by muse, mutect2, varscan2
- NRXN3 | c.2233C>T p.L745F (on ENST00000335750 / NM_001330195.2; = p.L372F on NM_004796.6) | Missense Mutation (SNP) | VAF 146/324 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1395369281; called by muse, mutect2, varscan2
- NSUN7 | c.254C>T p.S85F | Missense Mutation (SNP) | VAF 146/312 reads (47%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV57273195; called by muse, mutect2, varscan2
- NTRK1 | c.1814G>A p.G605E | Missense Mutation (SNP) | VAF 157/363 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV62323342; called by muse, mutect2, varscan2
- NUMA1 | c.1364G>A p.G455D | Missense Mutation (SNP) | VAF 188/410 reads (46%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as rs34441100; called by muse, mutect2, varscan2
- NUP160 | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 139/310 reads (45%) | SIFT tolerated (0.72); PolyPhen benign (0.055); catalogued as rs1044404400; called by muse, mutect2, varscan2
- NUP210 | c.3281C>T p.A1094V | Missense Mutation (SNP) | VAF 166/363 reads (46%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs1259305189; called by muse, mutect2, varscan2
- NUP214 | c.1448C>T p.S483F | Missense Mutation (SNP) | VAF 188/342 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.047); catalogued as rs966373971; called by muse, mutect2, varscan2
- NXF1 | c.1705G>A p.E569K | Missense Mutation (SNP) | VAF 180/407 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.111); catalogued as rs372102791; called by muse, mutect2, varscan2
- NYAP2 | c.499G>A p.G167R | Missense Mutation (SNP) | VAF 145/284 reads (51%) | SIFT tolerated (0.33); PolyPhen benign (0.29); catalogued as rs370336845; called by muse, mutect2, varscan2
- NYNRIN | c.1991C>T p.A664V | Missense Mutation (SNP) | VAF 183/399 reads (46%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as rs1433103582; called by muse, mutect2, varscan2
- OBI1 | c.850G>A p.G284S | Missense Mutation (SNP) | VAF 133/280 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs754165917; called by muse, mutect2, varscan2
- OBSCN | c.2206G>A p.A736T | Missense Mutation (SNP) | VAF 287/560 reads (51%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.696); catalogued as COSV52736172; called by muse, mutect2, varscan2
- OBSCN | c.11023G>A p.D3675N | Missense Mutation (SNP) | VAF 179/365 reads (49%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.973); catalogued as rs760822735; called by muse, mutect2, varscan2
- OCSTAMP | c.34G>A p.V12I | Missense Mutation (SNP) | VAF 162/491 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs937395451; called by muse, mutect2, varscan2
- ODF3 | c.194C>T p.S65F | Missense Mutation (SNP) | VAF 256/490 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57295408; called by muse, mutect2, varscan2
- OGN | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 108/200 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs1213054483; called by muse, mutect2, varscan2
- OLFML2A | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 123/300 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.835); catalogued as rs1273902614; called by muse, mutect2, varscan2
- ONECUT2 | c.136G>A p.G46R | Missense Mutation (SNP) | VAF 60/113 reads (53%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs755937360; called by muse, mutect2, varscan2
- OR10AC1 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 98/1054 reads (9%) | SIFT tolerated, low confidence (1); catalogued as rs1314590926; called by muse, mutect2
- OR14I1 | c.842C>T p.P281L | Missense Mutation (SNP) | VAF 99/237 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs141771834; called by muse, mutect2, varscan2
4,672 further variants in this file (2,706 protein-altering or splice-affecting, 1,735 silent, 231 other) are not listed here.
